Somatic mutation profile of tumor specimen TCGA-AZ-4615-01A (aliquot TCGA-AZ-4615-01A-01D-1408-10) from TCGA case TCGA-AZ-4615, project TCGA-COAD (Colon Adenocarcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Cecum; AJCC pathologic stage: Stage IIIB; Age at diagnosis: 84.6 years (30,908 days).
Specimen TCGA-AZ-4615-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) af3a55d3-a3b2-480b-8600-d948e65bcc70.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-AZ-4615-10A (Blood Derived Normal), aliquot TCGA-AZ-4615-10A-01D-2188-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/5c6eb6ba-7cf3-4eae-909f-8b3d2955b627

The open-access MAF lists 1,257 somatic variants for this specimen: 951 protein-altering or splice-affecting, 276 silent, 30 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 612, Silent 276, Frame Shift Del 217, Frame Shift Ins 42, Nonsense Mutation 30, Splice Site 22, Splice Region 14, Intron 14, In Frame Del 10, RNA 9, 3'UTR 5, Nonstop Mutation 2.

Variants (750 of 1,257; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- AMH | c.208dup p.L70Pfs*11 | Frame Shift Ins (INS) | VAF 12/24 reads (50%) | catalogued as rs769922506; ClinVar: pathogenic; called by mutect2, pindel, varscan2
- BRAF | c.1919T>A p.V640E (on ENST00000288602 / NM_001374244.1; = p.V600E on NM_004333.6 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 26/51 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); catalogued as rs113488022, CM112509, COSV56056643, COSV56065204, COSV56080151; ClinVar: pathogenic / likely pathogenic / other / drug response; called by muse, mutect2, varscan2
- DOK7 | c.1263del p.S422Hfs*34 | Frame Shift Del (DEL) | VAF 12/31 reads (39%) | catalogued as rs606231129; ClinVar: pathogenic; called by mutect2, pindel, varscan2
- FANCA | c.2851C>T p.R951W | Missense Mutation (SNP) | VAF 10/36 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs755546887, CM050609, COSV59795674; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- FLCN | c.1285del p.H429Tfs*39 | Frame Shift Del (DEL) | VAF 21/29 reads (72%) | catalogued as rs80338682, CD023282, CM082680; ClinVar: pathogenic; called by mutect2, varscan2
- GDAP1 | c.579+1G>A p.X193_splice | Splice Site (SNP) | VAF 7/28 reads (25%) | catalogued as rs864622501, CS032411, COSV55184944; ClinVar: uncertain significance / pathogenic; called by muse, mutect2
- IQSEC2 | c.848del p.G283Afs*23 (on ENST00000642864 / NM_001111125.3; = p.G78Afs*23 on NM_015075.2) | Frame Shift Del (DEL) | VAF 9/16 reads (56%) | catalogued as rs782660318, COSV64726734; ClinVar: pathogenic; called by mutect2, pindel, varscan2
- KMT2A | c.2318dup p.S774Vfs*12 | Frame Shift Ins (INS) | VAF 28/104 reads (27%) | catalogued as rs782297546; ClinVar: pathogenic; called by mutect2, varscan2
- MYH11 | c.5787-4707del | Intron (DEL) | VAF 12/40 reads (30%) | catalogued as rs747392139, COSV100257523; ClinVar: uncertain significance / benign / likely benign / likely pathogenic; called by mutect2, varscan2
- OAT | c.1250C>T p.P417L | Missense Mutation (SNP) | VAF 33/74 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs121965044, CM920530, COSV64347933; ClinVar: pathogenic; called by muse, mutect2, varscan2
- POMGNT1 | c.187C>T p.R63* | Nonsense Mutation (SNP) | VAF 9/107 reads (8%) | catalogued as rs193919337, CM030725, COSV64339395; ClinVar: pathogenic; called by muse, mutect2
- SCN1A | c.5734C>T p.R1912* (on ENST00000303395 / NM_001202435.3; = p.R1901* on NM_006920.6 and 1 other RefSeq transcript) | Nonsense Mutation (SNP) | VAF 31/105 reads (30%) | catalogued as rs77216276, CD114895, CM044053, COSV57661348; ClinVar: pathogenic; called by muse, mutect2, varscan2
- SPAST | c.631G>A p.V211I | Missense Mutation (SNP) | VAF 36/102 reads (35%) | SIFT tolerated (0.3); PolyPhen benign (0.052); catalogued as rs143003434, COSV59518422; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- TSC1 | c.1257del p.R420Gfs*20 | Frame Shift Del (DEL) | VAF 19/43 reads (44%) | catalogued as rs118203506, CD991903; ClinVar: not provided / pathogenic; called by mutect2, pindel, varscan2
- AAR2 | c.662C>T p.T221M | Missense Mutation (SNP) | VAF 18/37 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as rs1486657267, COSV57923583; called by muse, mutect2, varscan2
- AASDH | c.1303G>T p.G435* | Nonsense Mutation (SNP) | VAF 25/67 reads (37%) | catalogued as COSV52704290; called by muse, mutect2, varscan2
- AASDH | c.342dup p.Q115Tfs*3 | Frame Shift Ins (INS) | VAF 28/81 reads (35%) | catalogued as rs376463919; called by mutect2, varscan2
- ABCA1 | c.4069T>C p.F1357L | Missense Mutation (SNP) | VAF 10/26 reads (38%) | SIFT deleterious (0); PolyPhen possibly damaging (0.835); catalogued as COSV66064158; called by muse, mutect2, varscan2
- ABCA5 | c.1786C>T p.Q596* | Nonsense Mutation (SNP) | VAF 16/65 reads (25%) | catalogued as COSV67015903; called by muse, mutect2, varscan2
- ABCB1 | c.3253C>T p.R1085W | Missense Mutation (SNP) | VAF 4/16 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs199943026, COSV55947837; called by mutect2, varscan2
- ABCC12 | c.3106C>A p.L1036I | Missense Mutation (SNP) | VAF 35/87 reads (40%) | SIFT tolerated (0.19); PolyPhen benign (0.012); catalogued as COSV60912033; called by muse, mutect2, varscan2
- ABCC9 | c.2978T>C p.L993P | Missense Mutation (SNP) | VAF 32/78 reads (41%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.649); catalogued as COSV53963865; called by muse, mutect2, varscan2
- AC011455.2 | c.1250A>G p.H417R | Missense Mutation (SNP) | VAF 17/62 reads (27%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.964); catalogued as COSV55498502; called by muse, mutect2, varscan2
- ACAA1 | c.1105del p.L369Wfs*7 | Frame Shift Del (DEL) | VAF 9/38 reads (24%) | catalogued as COSV100086020; called by mutect2, pindel, varscan2
- ACSF3 | c.116G>A p.R39H | Missense Mutation (SNP) | VAF 7/19 reads (37%) | SIFT tolerated (0.55); PolyPhen benign (0); catalogued as rs144711526; called by muse, mutect2, varscan2
- ACTL7A | c.1088del p.G363Afs*16 | Frame Shift Del (DEL) | VAF 9/38 reads (24%) | catalogued as COSV100453203; called by mutect2, pindel, varscan2
- ACTL7B | c.812G>A p.G271D | Missense Mutation (SNP) | VAF 10/26 reads (38%) | SIFT tolerated (0.27); PolyPhen benign (0.081); catalogued as COSV65926900, COSV65928365; called by muse, mutect2, varscan2
- ADA | c.170C>G p.T57S | Missense Mutation (SNP) | VAF 9/36 reads (25%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV100866585; called by muse, mutect2, varscan2
- ADAM11 | c.104dup p.P37Tfs*10 | Frame Shift Ins (INS) | VAF 10/23 reads (43%) | catalogued as rs767694891; called by mutect2, varscan2
- ADAM20 | c.289G>A p.A97T | Missense Mutation (SNP) | VAF 22/67 reads (33%) | SIFT deleterious (0.05); PolyPhen benign (0.196); catalogued as rs772919007, COSV56454193; called by muse, mutect2, varscan2
- ADAM23 | c.1609G>A p.G537R | Missense Mutation (SNP) | VAF 33/82 reads (40%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.952); catalogued as rs147866783, COSV52209696; called by muse, mutect2, varscan2
- ADAM32 | c.750G>T p.E250D | Missense Mutation (SNP) | VAF 34/125 reads (27%) | SIFT tolerated (0.27); PolyPhen benign (0.071); catalogued as COSV65947444; called by muse, mutect2, varscan2
- ADAM32 | c.1238G>A p.C413Y | Missense Mutation (SNP) | VAF 16/60 reads (27%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV65947448; called by muse, mutect2, varscan2
- ADAMDEC1 | c.1022del p.K341Rfs*7 | Frame Shift Del (DEL) | VAF 30/56 reads (54%) | catalogued as rs746174250; called by mutect2, varscan2
- ADAMTS16 | c.2172T>G p.N724K | Missense Mutation (SNP) | VAF 40/108 reads (37%) | SIFT tolerated (0.07); PolyPhen benign (0.057); catalogued as COSV56980125, COSV57006484; called by muse, mutect2, varscan2
- ADAMTS5 | c.772C>T p.R258W | Missense Mutation (SNP) | VAF 6/8 reads (75%) | SIFT deleterious (0); PolyPhen probably damaging (0.965); catalogued as rs1404688513, COSV53176244; called by muse, mutect2
- AGAP1 | c.386del p.P129Rfs*22 | Frame Shift Del (DEL) | VAF 24/72 reads (33%) | catalogued as COSV58317085; called by mutect2, pindel, varscan2
- AHNAK2 | c.2483C>T p.A828V | Missense Mutation (SNP) | VAF 47/114 reads (41%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.804); catalogued as COSV60908971; called by muse, mutect2, varscan2
- AKAP12 | c.5034T>A p.D1678E | Missense Mutation (SNP) | VAF 38/96 reads (40%) | SIFT tolerated (0.15); PolyPhen benign (0); catalogued as COSV53570671; called by muse, mutect2, varscan2
- AKAP13 | c.8045G>A p.R2682Q (on ENST00000394518 / NM_007200.5; = p.R2686Q on NM_006738.6) | Missense Mutation (SNP) | VAF 14/49 reads (29%) | SIFT tolerated (0.43); PolyPhen benign (0.003); catalogued as rs772008595, COSV63449850; called by muse, mutect2, varscan2
- AKAP7 | c.236del p.K79Rfs*21 | Frame Shift Del (DEL) | VAF 114/168 reads (68%) | catalogued as rs763109484, COSV100818792; called by mutect2, varscan2
- AKR1C3 | c.196C>T p.R66* | Nonsense Mutation (SNP) | VAF 35/92 reads (38%) | catalogued as rs782405598, COSV65910106; called by muse, mutect2, varscan2
- AKR7A2 | c.848C>T p.A283V | Missense Mutation (SNP) | VAF 18/56 reads (32%) | SIFT tolerated (0.44); PolyPhen benign (0.009); catalogued as COSV52515736; called by muse, varscan2
- AKT2 | c.803C>T p.S268L | Missense Mutation (SNP) | VAF 4/22 reads (18%) | SIFT tolerated (0.07); PolyPhen benign (0.082); catalogued as rs757245351, COSV100251543; called by mutect2, varscan2
- ALAD | c.859C>T p.H287Y | Missense Mutation (SNP) | VAF 17/45 reads (38%) | SIFT tolerated (0.99); PolyPhen benign (0.127); catalogued as COSV52958057; called by muse, mutect2, varscan2
- ALDH9A1 | c.1508A>G p.Q503R | Missense Mutation (SNP) | VAF 16/51 reads (31%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.989); catalogued as COSV61339160; called by muse, mutect2, varscan2
- ALKBH4 | c.518C>T p.A173V | Missense Mutation (SNP) | VAF 8/16 reads (50%) | SIFT tolerated (0.59); PolyPhen benign (0.013); catalogued as rs1027485108, COSV52960481; called by muse, mutect2, varscan2
- ALOX12 | c.1826A>G p.H609R | Missense Mutation (SNP) | VAF 8/30 reads (27%) | SIFT tolerated (0.13); PolyPhen benign (0.41); catalogued as COSV99278023; called by mutect2, varscan2
- ANAPC7 | c.1189C>T p.R397W | Missense Mutation (SNP) | VAF 8/27 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1362231209, COSV71443723; called by muse, mutect2, varscan2
- ANGPTL1 | c.248T>C p.M83T | Missense Mutation (SNP) | VAF 82/195 reads (42%) | SIFT tolerated (0.7); PolyPhen benign (0.017); catalogued as COSV52365571; called by muse, mutect2, varscan2
- ANKRD11 | c.5576C>T p.S1859L | Missense Mutation (SNP) | VAF 11/27 reads (41%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.817); catalogued as rs767688937, COSV56355898; called by muse, mutect2, varscan2
- ANKRD50 | c.1160G>T p.R387L | Missense Mutation (SNP) | VAF 35/97 reads (36%) | SIFT tolerated (0.05); PolyPhen benign (0.097); catalogued as COSV72385123, COSV72385938; called by muse, mutect2, varscan2
- ANKRD55 | c.1121A>G p.D374G | Missense Mutation (SNP) | VAF 59/197 reads (30%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0); catalogued as rs770663123, COSV61947501; called by muse, mutect2, varscan2
- AP5Z1 | c.2086dup p.Q696Pfs*67 | Frame Shift Ins (INS) | VAF 10/26 reads (38%) | catalogued as rs771683676; called by mutect2, varscan2
- APBA2 | c.11G>A p.R4Q | Missense Mutation (SNP) | VAF 19/36 reads (53%) | SIFT deleterious, low confidence (0.03); PolyPhen probably damaging (0.984); catalogued as rs777078546, CM0910141, COSV101382135, COSV68789125; called by muse, mutect2, varscan2
- APBB1 | c.1840G>A p.V614M | Missense Mutation (SNP) | VAF 11/37 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1349575692, COSV54966697; called by muse, mutect2, varscan2
- APOB | c.13154G>A p.R4385H | Missense Mutation (SNP) | VAF 49/148 reads (33%) | SIFT tolerated (0.15); PolyPhen benign (0.014); catalogued as rs533755016, CM055088, COSV51925197; ClinVar: conflicting interpretations of pathogenicity; called by muse, mutect2, varscan2
- APOBEC3C | c.167G>A p.R56Q | Missense Mutation (SNP) | VAF 4/15 reads (27%) | SIFT tolerated (0.38); PolyPhen benign (0.079); catalogued as rs919511151, COSV63865237; called by muse, mutect2, varscan2
- APOBEC3H | c.428A>G p.D143G | Missense Mutation (SNP) | VAF 7/23 reads (30%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.95); catalogued as COSV100818807; called by muse, mutect2, varscan2
- APOOL | c.13A>G p.R5G | Missense Mutation (SNP) | VAF 15/22 reads (68%) | SIFT deleterious (0.01); PolyPhen benign (0.037); catalogued as COSV64271595; called by muse, mutect2, varscan2
- AQP9 | c.227G>A p.G76D | Missense Mutation (SNP) | VAF 25/85 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV54967711; called by muse, mutect2, varscan2
- ARF1 | c.11T>G p.I4S | Missense Mutation (SNP) | VAF 15/35 reads (43%) | SIFT tolerated, low confidence (0.59); PolyPhen benign (0.003); catalogued as COSV55254187; called by muse, mutect2, varscan2
- ARFGAP2 | c.276del p.R93Afs*43 | Frame Shift Del (DEL) | VAF 35/97 reads (36%) | catalogued as rs772728725, COSV54066450; called by mutect2, pindel, varscan2
- ARHGEF11 | c.1118C>T p.A373V | Missense Mutation (SNP) | VAF 19/50 reads (38%) | SIFT deleterious (0); PolyPhen possibly damaging (0.871); catalogued as rs768597800, COSV63810625; called by muse, mutect2, varscan2
- ARMC4 | c.1832G>T p.G611V | Missense Mutation (SNP) | VAF 12/33 reads (36%) | SIFT deleterious (0); PolyPhen possibly damaging (0.883); catalogued as COSV59457397, COSV59465859; called by muse, mutect2, varscan2
- ARR3 | c.1057C>T p.P353S | Missense Mutation (SNP) | VAF 28/42 reads (67%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV52103304; called by muse, mutect2, varscan2
- ARSD | c.680C>T p.A227V | Missense Mutation (SNP) | VAF 17/27 reads (63%) | SIFT tolerated (0.11); PolyPhen benign (0.069); catalogued as rs776826306, COSV54198582; called by muse, mutect2, varscan2
- ASAH2 | c.148del p.S50Qfs*40 | Frame Shift Del (DEL) | VAF 36/86 reads (42%) | catalogued as rs772181094; called by mutect2, varscan2
- ASPG | c.934A>G p.M312V | Missense Mutation (SNP) | VAF 19/51 reads (37%) | SIFT tolerated (0.14); PolyPhen benign (0.173); catalogued as rs749415102, COSV71933590; called by muse, mutect2, varscan2
- ATAD5 | c.4078-2A>G p.X1360_splice | Splice Site (SNP) | VAF 34/94 reads (36%) | catalogued as COSV58972359; called by muse, mutect2, varscan2
- ATF5 | c.711G>T p.E237D | Missense Mutation (SNP) | VAF 16/41 reads (39%) | SIFT tolerated (0.31); PolyPhen benign (0.066); catalogued as COSV61311093; called by muse, mutect2, varscan2
- ATG13 | c.1547T>C p.L516P (on ENST00000359513 / NM_001346321.1; = p.L479P on NM_014741.4 and 9 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 22/50 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV56317780; called by muse, mutect2, varscan2
- ATG2A | c.1966C>T p.P656S | Missense Mutation (SNP) | VAF 6/15 reads (40%) | SIFT tolerated (0.19); PolyPhen benign (0); catalogued as rs747149594, COSV65966001; called by muse, mutect2, varscan2
- ATG2B | c.3523G>A p.V1175I | Missense Mutation (SNP) | VAF 54/137 reads (39%) | SIFT tolerated (0.31); PolyPhen probably damaging (0.979); catalogued as rs757400421, COSV99951998; called by muse, mutect2, varscan2
- ATG2B | c.2438-2dup p.X813_splice | Splice Site (INS) | VAF 6/24 reads (25%) | catalogued as COSV63425553; called by pindel, varscan2
- ATIC | c.71T>C p.L24P | Missense Mutation (SNP) | VAF 23/70 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52692025; called by muse, mutect2, varscan2
- ATP8A2 | c.887T>C p.M296T | Missense Mutation (SNP) | VAF 31/85 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.946); catalogued as COSV99681339; called by muse, mutect2, varscan2
- AUTS2 | c.277A>G p.M93V | Missense Mutation (SNP) | VAF 21/53 reads (40%) | SIFT deleterious (0.01); PolyPhen benign (0.026); catalogued as rs779944756, COSV61385714; called by muse, mutect2, varscan2
- B3GNT8 | c.1135G>T p.G379C | Missense Mutation (SNP) | VAF 29/79 reads (37%) | SIFT deleterious (0.01); PolyPhen benign (0.115); catalogued as rs1349324048, COSV54195692; called by muse, mutect2, varscan2
- B4GALNT1 | c.1447C>T p.H483Y | Missense Mutation (SNP) | VAF 14/50 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV57541493; called by muse, mutect2, varscan2
- BACH1 | c.136C>A p.R46S | Missense Mutation (SNP) | VAF 21/52 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.909); catalogued as COSV54517507, COSV99728190; called by muse, mutect2, varscan2
- BAHD1 | c.469C>T p.R157C | Missense Mutation (SNP) | VAF 15/40 reads (38%) | SIFT tolerated (0.07); PolyPhen benign (0.003); catalogued as rs750392067, COSV69083682; called by muse, mutect2, varscan2
- BBS2 | c.1990A>T p.N664Y | Missense Mutation (SNP) | VAF 46/145 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV55325332; called by muse, mutect2, varscan2
- BEND2 | c.2182C>T p.R728* | Nonsense Mutation (SNP) | VAF 39/54 reads (72%) | catalogued as rs998503311, COSV66215175; called by muse, mutect2, varscan2
- BIRC6 | c.8513A>C p.K2838T | Missense Mutation (SNP) | VAF 23/42 reads (55%) | SIFT deleterious (0); PolyPhen probably damaging (0.961); catalogued as COSV101428131; called by muse, mutect2, varscan2
- BLK | c.166C>A p.L56M | Missense Mutation (SNP) | VAF 13/34 reads (38%) | SIFT tolerated (0.12); PolyPhen benign (0.17); catalogued as COSV52049775, COSV52053071; called by muse, mutect2, varscan2
- BMPR2 | c.1748del p.N583Tfs*44 | Frame Shift Del (DEL) | VAF 52/88 reads (59%) | catalogued as rs772920507, COSV65808737; called by mutect2, pindel, varscan2
- BNC2 | c.2633G>A p.R878Q | Missense Mutation (SNP) | VAF 8/38 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as rs1180035312, COSV66146216; called by muse, mutect2
- BOC | c.1592A>C p.Q531P | Missense Mutation (SNP) | VAF 11/48 reads (23%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.864); catalogued as COSV99848521; called by muse, mutect2, varscan2
- BRDT | c.1460+4_1460+7del p.X487_splice | Splice Site (DEL) | VAF 70/252 reads (28%) | catalogued as rs1177678095; called by pindel, varscan2
- BTN3A3 | c.55T>C p.F19L | Missense Mutation (SNP) | VAF 12/90 reads (13%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs1006302093, COSV55072206; called by muse, mutect2
- C11orf54 | c.810del p.F270Lfs*18 (on ENST00000331239; = p.F220Lfs*18 on NM_014039.4 and 1 other RefSeq transcript) | Frame Shift Del (DEL) | VAF 31/83 reads (37%) | catalogued as rs1243082072; called by mutect2, pindel, varscan2
- C11orf87 | c.532G>A p.A178T | Missense Mutation (SNP) | VAF 10/37 reads (27%) | SIFT tolerated, low confidence (0.29); PolyPhen benign (0.001); catalogued as COSV59356192; called by muse, mutect2, varscan2
- C16orf89 | c.782G>A p.G261D | Missense Mutation (SNP) | VAF 26/69 reads (38%) | SIFT deleterious (0.01); PolyPhen benign (0.397); catalogued as rs770082606, COSV60122366; called by muse, mutect2, varscan2
- C1QL2 | c.508G>A p.E170K | Missense Mutation (SNP) | VAF 17/48 reads (35%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.983); catalogued as COSV55606064; called by muse, mutect2, varscan2
- C2orf15 | c.-77+2T>C | Splice Site (SNP) | VAF 22/62 reads (35%) | catalogued as COSV56781503; called by muse, mutect2, varscan2
- C4B | c.4046G>A p.R1349H | Missense Mutation (SNP) | VAF 14/48 reads (29%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs1488789901; called by mutect2, varscan2
- C6orf118 | c.704A>G p.D235G | Missense Mutation (SNP) | VAF 10/26 reads (38%) | SIFT tolerated (0.06); PolyPhen benign (0.229); catalogued as COSV57812860; called by mutect2, varscan2
- CA1 | c.715G>A p.A239T | Missense Mutation (SNP) | VAF 13/71 reads (18%) | SIFT tolerated (0.3); PolyPhen benign (0.333); catalogued as rs141945543; called by muse, mutect2, varscan2
- CADPS | c.3154G>A p.A1052T | Missense Mutation (SNP) | VAF 36/115 reads (31%) | SIFT tolerated (0.2); PolyPhen benign (0); catalogued as COSV51869190; called by muse, mutect2, varscan2
- CAMKV | c.1286C>G p.A429G | Missense Mutation (SNP) | VAF 24/83 reads (29%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0); catalogued as COSV56554224; called by muse, mutect2, varscan2
- CAMSAP3 | c.2584G>A p.G862R | Missense Mutation (SNP) | VAF 5/16 reads (31%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.965); catalogued as rs902868104, COSV50331249; called by muse, mutect2, varscan2
- CAPRIN1 | c.1823G>A p.R608H | Missense Mutation (SNP) | VAF 24/51 reads (47%) | SIFT deleterious (0); PolyPhen possibly damaging (0.812); catalogued as rs1304276359, COSV58218676; called by muse, mutect2, varscan2
- CAPZA1 | c.808G>A p.D270N | Missense Mutation (SNP) | VAF 47/71 reads (66%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.986); catalogued as rs773856348, COSV54144396; called by muse, mutect2, varscan2
- CASKIN2 | c.2182del p.Q728Rfs*74 | Frame Shift Del (DEL) | VAF 7/28 reads (25%) | catalogued as rs751998890, COSV100051067; called by mutect2, varscan2
- CBX6 | c.244A>G p.K82E | Missense Mutation (SNP) | VAF 8/37 reads (22%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.704); catalogued as COSV99328081; called by muse, mutect2, varscan2
- CCDC59 | c.724T>C p.*242Qext*26 | Nonstop Mutation (SNP) | VAF 11/130 reads (8%) | catalogued as COSV56280748; called by muse, mutect2
- CCDC88A | c.2032dup p.T678Nfs*4 | Frame Shift Ins (INS) | VAF 32/108 reads (30%) | catalogued as rs750732366; called by mutect2, varscan2
- CCDC9 | c.1099C>T p.R367C | Missense Mutation (SNP) | VAF 14/40 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs368896025; called by muse, mutect2, varscan2
- CCNP | c.149C>T p.A50V | Missense Mutation (SNP) | VAF 5/20 reads (25%) | SIFT tolerated (0.14); PolyPhen benign (0); catalogued as COSV99695850; called by muse, mutect2, varscan2
- CCSAP | c.617C>T p.A206V | Missense Mutation (SNP) | VAF 38/149 reads (26%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs1414465475, COSV52909113; called by muse, mutect2, varscan2
- CD74 | c.311T>C p.V104A | Missense Mutation (SNP) | VAF 12/44 reads (27%) | SIFT tolerated (0.36); PolyPhen benign (0.009); catalogued as COSV50532160; called by muse, varscan2
- CD99 | c.409G>A p.A137T | Missense Mutation (SNP) | VAF 22/56 reads (39%) | SIFT tolerated (0.73); PolyPhen probably damaging (0.994); catalogued as rs188016181, COSV66989201; called by muse, mutect2, varscan2
- CDC40 | c.952G>T p.V318F | Missense Mutation (SNP) | VAF 57/170 reads (34%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.98); catalogued as COSV57008034; called by muse, mutect2, varscan2
- CDC42BPB | c.2300C>T p.A767V | Missense Mutation (SNP) | VAF 49/128 reads (38%) | SIFT tolerated (0.39); PolyPhen benign (0); catalogued as rs374402137; called by muse, mutect2, varscan2
- CDHR2 | c.3274C>T p.R1092W | Missense Mutation (SNP) | VAF 23/51 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs1438878369, COSV56135159; called by muse, mutect2, varscan2
- CDK5RAP2 | c.1141G>A p.A381T | Missense Mutation (SNP) | VAF 42/101 reads (42%) | SIFT tolerated (0.1); PolyPhen benign (0.284); catalogued as COSV62572364; called by muse, mutect2, varscan2
- CDK9 | c.627dup p.I210Hfs*2 | Frame Shift Ins (INS) | VAF 11/44 reads (25%) | catalogued as rs755440676; called by mutect2, varscan2
- CELF4 | c.622G>A p.A208T | Missense Mutation (SNP) | VAF 5/9 reads (56%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV58447637; called by muse, mutect2, varscan2
- CEP104 | c.407A>G p.K136R | Missense Mutation (SNP) | VAF 42/128 reads (33%) | SIFT tolerated (0.46); PolyPhen benign (0.024); catalogued as COSV65511904; called by muse, mutect2, varscan2
- CEP170B | c.1933del p.Q645Rfs*179 (on ENST00000453495; = p.Q574Rfs*179 on NM_015005.3) | Frame Shift Del (DEL) | VAF 8/20 reads (40%) | catalogued as rs1431118175; called by mutect2, pindel
- CFAP298-TCP10L | c.640del p.T214Pfs*40 | Frame Shift Del (DEL) | VAF 39/122 reads (32%) | catalogued as COSV51593519; called by mutect2, pindel, varscan2
- CHD3 | c.254G>A p.R85Q | Missense Mutation (SNP) | VAF 26/70 reads (37%) | SIFT tolerated, low confidence (0.22); PolyPhen benign (0.042); catalogued as rs758459375, COSV57872921; called by muse, mutect2, varscan2
- CHIC1 | c.63_65dup p.E24dup | In Frame Ins (INS) | VAF 7/10 reads (70%) | catalogued as rs773550444; called by mutect2, varscan2
- CHRD | c.1963G>A p.G655R | Missense Mutation (SNP) | VAF 6/13 reads (46%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.79); catalogued as rs377545047, COSV52605882; called by muse, mutect2, varscan2
- CINP | c.288G>T p.Q96H | Missense Mutation (SNP) | VAF 15/131 reads (11%) | SIFT tolerated (0.17); PolyPhen benign (0.009); catalogued as COSV53736103; called by muse, mutect2, varscan2
- CLASP1 | c.382G>A p.V128I | Missense Mutation (SNP) | VAF 27/59 reads (46%) | SIFT tolerated (0.39); PolyPhen benign (0.009); catalogued as rs769674332, COSV55315336; called by muse, mutect2, varscan2
- CNOT1 | c.5786G>A p.R1929Q | Missense Mutation (SNP) | VAF 12/38 reads (32%) | SIFT deleterious (0); PolyPhen benign (0.237); catalogued as rs746289649, COSV55313743; called by muse, mutect2, varscan2
- CNOT6 | c.1355A>G p.H452R | Missense Mutation (SNP) | VAF 36/125 reads (29%) | SIFT tolerated (0.17); PolyPhen benign (0.003); catalogued as rs141532758; called by muse, mutect2, varscan2
- CNTN2 | c.1052C>G p.A351G | Missense Mutation (SNP) | VAF 12/31 reads (39%) | SIFT deleterious (0.01); PolyPhen benign (0); catalogued as COSV59348381; called by muse, mutect2, varscan2
- CNTN4 | c.2656G>T p.G886C | Missense Mutation (SNP) | VAF 64/192 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV61868666, COSV61875675; called by muse, mutect2, varscan2
- CNTRL | c.1730G>A p.R577H | Missense Mutation (SNP) | VAF 27/73 reads (37%) | SIFT tolerated (0.15); PolyPhen probably damaging (0.996); catalogued as COSV53044080; called by muse, mutect2, varscan2
- CNTROB | c.1528C>T p.R510* | Nonsense Mutation (SNP) | VAF 13/84 reads (15%) | catalogued as rs780789745, COSV66607662; called by muse, mutect2, varscan2
- COL15A1 | c.3391T>G p.S1131A | Missense Mutation (SNP) | VAF 79/195 reads (41%) | SIFT tolerated (0.17); PolyPhen benign (0.138); catalogued as COSV66641672; called by muse, mutect2, varscan2
- COL22A1 | c.308C>T p.A103V | Missense Mutation (SNP) | VAF 10/32 reads (31%) | SIFT tolerated (0.2); PolyPhen benign (0.278); catalogued as rs146310961; called by muse, mutect2, varscan2
- COL25A1 | c.19G>A p.A7T | Missense Mutation (SNP) | VAF 6/21 reads (29%) | SIFT tolerated, low confidence (0.21); PolyPhen benign (0.012); catalogued as COSV67646938; called by muse, varscan2
- COL2A1 | c.788C>A p.A263D | Missense Mutation (SNP) | VAF 5/26 reads (19%) | SIFT deleterious (0.02); PolyPhen benign (0.025); catalogued as COSV61528322, COSV61532054; called by muse, mutect2, varscan2
- COL6A3 | c.7834G>A p.A2612T | Missense Mutation (SNP) | VAF 22/53 reads (42%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as COSV55081279; called by muse, mutect2, varscan2
- CPED1 | c.106C>T p.R36* | Nonsense Mutation (SNP) | VAF 24/60 reads (40%) | catalogued as rs1240076249, COSV59997954; called by muse, mutect2, varscan2
- CPT1A | c.149T>C p.I50T | Missense Mutation (SNP) | VAF 20/38 reads (53%) | SIFT deleterious (0); PolyPhen benign (0.185); catalogued as COSV55753331; called by muse, mutect2, varscan2
- CPT1B | c.1241G>A p.R414H | Missense Mutation (SNP) | VAF 14/28 reads (50%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.849); catalogued as rs757229551, COSV56415320; called by muse, mutect2, varscan2
- CRHBP | c.292G>A p.D98N | Missense Mutation (SNP) | VAF 19/49 reads (39%) | SIFT tolerated (0.37); PolyPhen benign (0.048); catalogued as COSV57187634; called by muse, mutect2, varscan2
- CRTAC1 | c.758C>T p.A253V | Missense Mutation (SNP) | VAF 16/36 reads (44%) | SIFT tolerated (0.4); PolyPhen benign (0.192); catalogued as COSV53998066; called by muse, mutect2, varscan2
- CRTC3 | c.775C>A p.L259I | Missense Mutation (SNP) | VAF 44/120 reads (37%) | SIFT tolerated (0.53); PolyPhen benign (0.005); catalogued as COSV51594511; called by muse, mutect2, varscan2
- CRTC3 | c.1723G>A p.V575M | Missense Mutation (SNP) | VAF 26/56 reads (46%) | SIFT tolerated (0.3); PolyPhen benign (0.006); catalogued as rs771850121, COSV51594525; called by muse, mutect2, varscan2
- CRYBG1 | c.4492_4493del p.W1498Gfs*15 | Frame Shift Del (DEL) | VAF 62/187 reads (33%) | catalogued as COSV64810985; called by mutect2, pindel, varscan2
- CS | c.274C>T p.R92C | Missense Mutation (SNP) | VAF 12/34 reads (35%) | SIFT deleterious (0.03); PolyPhen benign (0.154); catalogued as rs779289848, COSV60832083, COSV60832337; called by muse, mutect2, varscan2
- CSF3R | c.754T>C p.C252R | Missense Mutation (SNP) | VAF 22/59 reads (37%) | SIFT tolerated (0.64); PolyPhen benign (0); catalogued as COSV58963805; called by muse, mutect2, varscan2
- CST4 | c.241dup p.V81Gfs*28 | Frame Shift Ins (INS) | VAF 18/70 reads (26%) | catalogued as rs767756120; called by mutect2, varscan2
- CUL7 | c.2854T>C p.C952R | Missense Mutation (SNP) | VAF 19/49 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV99538357; called by muse, mutect2, varscan2
- CUL9 | c.943C>T p.R315W | Missense Mutation (SNP) | VAF 9/29 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs765124435, COSV52725839; called by muse, mutect2, varscan2
- CYFIP2 | c.1315C>T p.R439C | Missense Mutation (SNP) | VAF 12/49 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as rs1476300276, COSV59029474; called by muse, mutect2, varscan2
- CYLC1 | c.301A>G p.R101G | Missense Mutation (SNP) | VAF 64/93 reads (69%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.478); catalogued as rs1391649005, COSV61410327; called by muse, mutect2, varscan2
- CYP2A6 | c.442C>T p.R148C | Missense Mutation (SNP) | VAF 13/25 reads (52%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.589); catalogued as rs1364382508, COSV56533987; called by muse, mutect2, varscan2
- CYP7B1 | c.446C>A p.S149Y | Missense Mutation (SNP) | VAF 29/88 reads (33%) | SIFT tolerated (0.72); PolyPhen possibly damaging (0.61); catalogued as rs762965007, COSV59583230, COSV59590216; called by muse, mutect2, varscan2
- CYREN | c.416C>A p.P139H | Missense Mutation (SNP) | VAF 6/29 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.867); catalogued as rs773641522, COSV51965663; called by muse, mutect2
- CYTH4 | c.1039G>T p.E347* | Nonsense Mutation (SNP) | VAF 12/45 reads (27%) | catalogued as COSV50631397, COSV50631425; called by muse, mutect2, varscan2
- DAB2IP | c.3073del p.H1025Tfs*5 (on ENST00000408936; = p.H997Tfs*5 on NM_032552.3) | Frame Shift Del (DEL) | VAF 6/8 reads (75%) | catalogued as rs751187768; called by mutect2, varscan2
- DAPK2 | c.508A>T p.I170F | Missense Mutation (SNP) | VAF 22/54 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as COSV56044031; called by muse, varscan2
- DCAF8L1 | c.526G>A p.A176T | Missense Mutation (SNP) | VAF 48/69 reads (70%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.829); catalogued as COSV71595151; called by muse, mutect2, varscan2
- DDI1 | c.231G>T p.K77N | Missense Mutation (SNP) | VAF 13/58 reads (22%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.511); catalogued as COSV56369885; called by muse, mutect2, varscan2
- DDI1 | c.854G>A p.R285Q | Missense Mutation (SNP) | VAF 20/55 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs778016206, COSV56369904; called by muse, mutect2, varscan2
- DDI2 | c.323G>A p.R108Q | Missense Mutation (SNP) | VAF 22/56 reads (39%) | SIFT tolerated (0.52); PolyPhen benign (0.003); catalogued as rs140092977; called by muse, mutect2, varscan2
- DDIAS | c.2398G>T p.D800Y | Missense Mutation (SNP) | VAF 29/96 reads (30%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.621); catalogued as rs1165471904, COSV61271605; called by muse, mutect2, varscan2
- DDX31 | c.532del p.M178Cfs*42 | Frame Shift Del (DEL) | VAF 55/165 reads (33%) | catalogued as rs1352828170; called by mutect2, pindel, varscan2
- DENND2C | c.644G>T p.R215M | Missense Mutation (SNP) | VAF 110/183 reads (60%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV67920217; called by muse, mutect2, varscan2
- DENND5A | c.1465C>T p.R489C | Missense Mutation (SNP) | VAF 41/101 reads (41%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.513); catalogued as rs557614928, COSV60231261; called by muse, mutect2, varscan2
- DES | c.259G>A p.E87K | Missense Mutation (SNP) | VAF 9/24 reads (38%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.933); catalogued as COSV64659918; called by muse, mutect2, varscan2
- DGCR8 | c.1321C>T p.R441* | Nonsense Mutation (SNP) | VAF 16/37 reads (43%) | catalogued as rs866121195, COSV61225818; called by muse, mutect2, varscan2
- DIAPH3 | c.892G>A p.V298I (on ENST00000400324 / NM_001042517.2; = p.V35I on NM_030932.3) | Missense Mutation (SNP) | VAF 13/30 reads (43%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.891); catalogued as COSV57365572; called by muse, mutect2, varscan2
- DIDO1 | c.6184G>A p.D2062N | Missense Mutation (SNP) | VAF 9/14 reads (64%) | SIFT deleterious (0.01); PolyPhen benign (0.007); catalogued as rs753441101, COSV56615016; called by muse, mutect2, varscan2
- DIP2C | c.2582G>A p.R861H | Missense Mutation (SNP) | VAF 13/27 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.92); catalogued as rs200146316, COSV55147971; called by muse, mutect2, varscan2
- DIRAS2 | c.337A>G p.S113G | Missense Mutation (SNP) | VAF 29/86 reads (34%) | SIFT tolerated (0.17); PolyPhen benign (0); catalogued as COSV65370020; called by muse, mutect2, varscan2
- DLEC1 | c.3002A>G p.Q1001R | Missense Mutation (SNP) | VAF 5/20 reads (25%) | SIFT tolerated (0.98); PolyPhen benign (0); catalogued as COSV100341931; called by muse, mutect2
- DLEC1 | c.3928del p.Y1310Mfs*121 | Frame Shift Del (DEL) | VAF 15/32 reads (47%) | catalogued as rs1559464249; called by mutect2, pindel, varscan2
- DLGAP2 | c.1502C>T p.A501V | Missense Mutation (SNP) | VAF 17/64 reads (27%) | SIFT tolerated (0.26); PolyPhen benign (0.009); catalogued as rs540100960, COSV70094821; called by muse, mutect2, varscan2
- DLK1 | c.532C>A p.P178T | Missense Mutation (SNP) | VAF 18/70 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57990759; called by muse, mutect2, varscan2
- DMAC1 | c.236del p.P79Rfs*59 | Frame Shift Del (DEL) | VAF 15/48 reads (31%) | catalogued as rs778030114, COSV64065840; called by mutect2, pindel, varscan2
- DMAC2L | c.205A>G p.R69G | Missense Mutation (SNP) | VAF 21/54 reads (39%) | SIFT deleterious (0); PolyPhen possibly damaging (0.567); catalogued as COSV55412836; called by muse, mutect2, varscan2
- DNAH11 | c.3332T>C p.V1111A | Missense Mutation (SNP) | VAF 39/140 reads (28%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.72); catalogued as COSV60942308; called by muse, mutect2, varscan2
- DNAH3 | c.11063G>A p.G3688D | Missense Mutation (SNP) | VAF 22/47 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV54506438; called by muse, mutect2, varscan2
- DNAJB8 | c.572G>A p.G191D | Missense Mutation (SNP) | VAF 16/56 reads (29%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.998); catalogued as rs373509985; called by muse, mutect2, varscan2
- DNAJC13 | c.3734C>A p.P1245Q | Missense Mutation (SNP) | VAF 22/78 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV53446453; called by muse, mutect2, varscan2
- DNAJC13 | c.3858G>T p.W1286C | Missense Mutation (SNP) | VAF 27/58 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV53446476; called by muse, mutect2, varscan2
- DOCK2 | c.3097G>A p.A1033T | Missense Mutation (SNP) | VAF 33/104 reads (32%) | SIFT tolerated (0.07); PolyPhen benign (0.297); catalogued as COSV56944590; called by muse, mutect2, varscan2
- DOCK3 | c.5555del p.P1852Qfs*45 | Frame Shift Del (DEL) | VAF 14/53 reads (26%) | catalogued as rs782552436; called by mutect2, varscan2
- DOK2 | c.790C>A p.L264M | Missense Mutation (SNP) | VAF 27/112 reads (24%) | SIFT tolerated (0.14); PolyPhen benign (0.051); catalogued as rs1450552503, COSV52387748; called by muse, mutect2, varscan2
- DPP10 | c.1978A>G p.I660V | Missense Mutation (SNP) | VAF 22/55 reads (40%) | SIFT tolerated (0.09); PolyPhen benign (0.048); catalogued as COSV59667512; called by muse, mutect2, varscan2
- DPP4 | c.288T>C p.D96= | Splice Region (SNP) | VAF 53/164 reads (32%) | catalogued as COSV62105362; called by muse, mutect2, varscan2
- DPP8 | c.2128C>T p.R710* (on ENST00000341861 / NM_001320875.2; = p.R694* on NM_130434.5 and 1 other RefSeq transcript) | Nonsense Mutation (SNP) | VAF 4/40 reads (10%) | catalogued as COSV55676419; called by mutect2, varscan2
- DPYSL5 | c.143C>A p.A48D | Missense Mutation (SNP) | VAF 39/98 reads (40%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.84); catalogued as COSV56509330; called by muse, mutect2, varscan2
- DSG4 | c.1743G>T p.M581I | Missense Mutation (SNP) | VAF 31/90 reads (34%) | SIFT tolerated (0.48); PolyPhen benign (0); catalogued as COSV57388871; called by muse, mutect2, varscan2
- DSN1 | c.335C>A p.P112H | Missense Mutation (SNP) | VAF 4/15 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); catalogued as COSV65518609; called by muse, mutect2, varscan2
- DST | c.8350G>A p.D2784N | Missense Mutation (SNP) | VAF 18/71 reads (25%) | SIFT tolerated, low confidence (0.16); PolyPhen benign (0.003); catalogued as COSV55008720; called by muse, mutect2, varscan2
- DST | c.7335T>G p.D2445E | Missense Mutation (SNP) | VAF 23/71 reads (32%) | SIFT tolerated, low confidence (0.29); PolyPhen benign (0.006); catalogued as COSV99754286; called by muse, mutect2, varscan2
- DUSP11 | c.355del p.S119Pfs*18 | Frame Shift Del (DEL) | VAF 26/86 reads (30%) | catalogued as rs762094663; called by mutect2, pindel, varscan2
- DYNC2H1 | c.10020G>T p.L3340F | Missense Mutation (SNP) | VAF 19/60 reads (32%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.951); catalogued as COSV62087556; called by muse, mutect2, varscan2
- DZIP1L | c.220C>T p.R74C | Missense Mutation (SNP) | VAF 10/31 reads (32%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.908); catalogued as rs147377503; called by muse, mutect2, varscan2
- E2F5 | c.320del p.K107Sfs*11 | Frame Shift Del (DEL) | VAF 11/48 reads (23%) | catalogued as rs761281897; called by mutect2, pindel, varscan2
- E4F1 | c.185G>A p.R62H | Missense Mutation (SNP) | VAF 40/118 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs776744880, COSV57037772; called by muse, mutect2, varscan2
- EBF2 | c.504C>A p.S168R | Missense Mutation (SNP) | VAF 28/114 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV68776331, COSV68777261; called by muse, mutect2, varscan2
- EEF1AKMT3 | c.295del p.X99_splice | Splice Site (DEL) | VAF 5/24 reads (21%) | catalogued as rs756314578; called by mutect2, pindel, varscan2
- EFEMP1 | c.377C>G p.A126G | Missense Mutation (SNP) | VAF 23/50 reads (46%) | SIFT tolerated (0.34); PolyPhen benign (0.069); catalogued as COSV62615194; called by muse, mutect2, varscan2
- EGR2 | c.20T>C p.V7A | Missense Mutation (SNP) | VAF 14/33 reads (42%) | SIFT tolerated (0.71); PolyPhen benign (0.007); catalogued as COSV54346298; called by muse, mutect2, varscan2
- EHMT1 | c.1861G>A p.V621I | Missense Mutation (SNP) | VAF 15/53 reads (28%) | SIFT tolerated (0.13); PolyPhen benign (0.001); catalogued as COSV58371452; called by muse, mutect2, varscan2
- ELFN2 | c.2281T>C p.Y761H | Missense Mutation (SNP) | VAF 20/61 reads (33%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.99); catalogued as COSV68743922; called by muse, mutect2, varscan2
- ELP4 | c.1148G>A p.R383Q (on ENST00000350638; = p.R382Q on NM_019040.5) | Missense Mutation (SNP) | VAF 17/55 reads (31%) | SIFT tolerated (0.14); PolyPhen benign (0.134); catalogued as rs776578960, COSV63350260; called by muse, mutect2, varscan2
- EML4 | c.387del p.E130Rfs*43 | Frame Shift Del (DEL) | VAF 10/34 reads (29%) | catalogued as rs770453803; called by mutect2, varscan2
- EP400 | c.985C>A p.P329T | Missense Mutation (SNP) | VAF 23/61 reads (38%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.295); catalogued as COSV100200965; called by muse, mutect2, varscan2
- EPB41L1 | c.2389G>A p.G797S | Missense Mutation (SNP) | VAF 20/47 reads (43%) | SIFT tolerated (0.59); PolyPhen benign (0.013); catalogued as rs746621229, COSV52434428; called by muse, mutect2, varscan2
- EPHA4 | c.1828C>T p.R610* | Nonsense Mutation (SNP) | VAF 58/127 reads (46%) | catalogued as COSV56027567; called by muse, mutect2, varscan2
- EPHA4 | c.1679T>A p.V560E | Missense Mutation (SNP) | VAF 19/47 reads (40%) | SIFT deleterious (0.01); PolyPhen benign (0.167); catalogued as COSV56027580; called by muse, mutect2, varscan2
- EPHA8 | c.1982A>G p.D661G | Missense Mutation (SNP) | VAF 15/54 reads (28%) | SIFT deleterious (0); PolyPhen benign (0.429); catalogued as COSV51263456; called by muse, mutect2, varscan2
- EQTN | c.77-3del | Splice Region (DEL) | VAF 55/139 reads (40%) | catalogued as rs768793415; called by mutect2, varscan2
- ERMN | c.574G>A p.D192N | Missense Mutation (SNP) | VAF 28/108 reads (26%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.891); catalogued as rs766036566, COSV68075015; called by muse, mutect2, varscan2
- ESPL1 | c.4231C>A p.L1411M | Missense Mutation (SNP) | VAF 12/25 reads (48%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.459); catalogued as COSV57757790; called by muse, mutect2, varscan2
- ETV4 | c.1224G>A p.M408I | Missense Mutation (SNP) | VAF 12/43 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV52251246; called by muse, mutect2, varscan2
- EXOC3 | c.460G>A p.G154R | Missense Mutation (SNP) | VAF 20/49 reads (41%) | SIFT deleterious (0.03); PolyPhen benign (0.13); catalogued as COSV59265678; called by muse, mutect2, varscan2
- EXOC4 | c.1267C>T p.R423* | Nonsense Mutation (SNP) | VAF 17/50 reads (34%) | catalogued as rs989563113, COSV54085638; called by muse, mutect2, varscan2
- EXTL1 | c.1577C>T p.T526M | Missense Mutation (SNP) | VAF 22/68 reads (32%) | SIFT tolerated (0.06); PolyPhen benign (0.227); catalogued as rs372060207; called by muse, mutect2, varscan2
- FAM167A | c.384G>A p.T128= | Splice Region (SNP) | VAF 11/31 reads (35%) | catalogued as rs533627555, COSV52667856; called by muse, mutect2, varscan2
- FAM189A2 | c.109C>T p.P37S | Missense Mutation (SNP) | VAF 39/128 reads (30%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.867); catalogued as COSV57383789; called by muse, mutect2, varscan2
- FAM193A | c.2497del p.M833Wfs*23 | Frame Shift Del (DEL) | VAF 30/96 reads (31%) | catalogued as rs768952789; called by mutect2, pindel, varscan2
- FAM50B | c.415G>A p.A139T | Missense Mutation (SNP) | VAF 12/33 reads (36%) | SIFT tolerated (0.19); PolyPhen benign (0.028); catalogued as rs768080374, COSV66654570, COSV66655272; called by muse, mutect2, varscan2
- FAM83G | c.2378C>T p.S793L | Missense Mutation (SNP) | VAF 16/48 reads (33%) | SIFT deleterious (0.03); PolyPhen benign (0.005); catalogued as rs538347250, COSV58755629; called by muse, mutect2, varscan2
- FANCA | c.3289G>A p.A1097T | Missense Mutation (SNP) | VAF 9/20 reads (45%) | SIFT tolerated (0.07); PolyPhen benign (0.084); catalogued as COSV59795666; called by muse, mutect2, varscan2
- FAP | c.1860A>G p.I620M | Missense Mutation (SNP) | VAF 55/185 reads (30%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.472); catalogued as rs1258832838, COSV51859643; called by muse, mutect2, varscan2
- FARS2 | c.772+2T>C p.X258_splice | Splice Site (SNP) | VAF 12/56 reads (21%) | catalogued as COSV51164800; called by muse, varscan2
- FAT1 | c.12819C>A p.F4273L | Missense Mutation (SNP) | VAF 14/47 reads (30%) | SIFT tolerated (0.45); PolyPhen probably damaging (0.986); catalogued as COSV71672201, COSV71672221; called by muse, mutect2, varscan2
- FAT2 | c.13030T>C p.C4344R | Missense Mutation (SNP) | VAF 17/52 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1307034849, COSV99942414; called by muse, mutect2
- FAT2 | c.3334A>G p.R1112G | Missense Mutation (SNP) | VAF 29/79 reads (37%) | SIFT tolerated (0.12); PolyPhen benign (0); catalogued as COSV55814419; called by muse, mutect2, varscan2
- FBN1 | c.92C>T p.A31V | Missense Mutation (SNP) | VAF 19/51 reads (37%) | SIFT tolerated (0.67); PolyPhen benign (0.007); catalogued as COSV57310565; called by muse, mutect2, varscan2
- FBN2 | c.6548C>A p.S2183* | Nonsense Mutation (SNP) | VAF 6/45 reads (13%) | catalogued as COSV52495701; called by muse, mutect2, varscan2
- FBXO28 | c.431C>T p.A144V | Missense Mutation (SNP) | VAF 9/28 reads (32%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.968); catalogued as COSV64799760; called by muse, mutect2, varscan2
- FCRL4 | c.658C>T p.R220W | Missense Mutation (SNP) | VAF 11/35 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs780000032, COSV54860054; called by muse, mutect2, varscan2
- FCRLB | c.395T>C p.V132A | Missense Mutation (SNP) | VAF 30/66 reads (45%) | SIFT deleterious (0); PolyPhen benign (0.033); catalogued as COSV61059390; called by muse, mutect2, varscan2
- FGFR1 | c.338A>G p.Y113C | Missense Mutation (SNP) | VAF 13/54 reads (24%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.907); catalogued as COSV58329053, COSV58342096; called by muse, mutect2, varscan2
- FGFRL1 | c.86del p.P29Qfs*32 | Frame Shift Del (DEL) | VAF 12/36 reads (33%) | catalogued as COSV99294743; called by mutect2, pindel, varscan2
- FKBP11 | c.462G>T p.K154N | Missense Mutation (SNP) | VAF 19/50 reads (38%) | SIFT tolerated (0.77); PolyPhen benign (0.001); catalogued as rs757467836, COSV56739198; called by muse, mutect2, varscan2
- FKBP4 | c.826C>T p.R276W | Missense Mutation (SNP) | VAF 24/57 reads (42%) | SIFT deleterious (0); PolyPhen possibly damaging (0.776); catalogued as rs372836178; called by muse, mutect2, varscan2
- FLG | c.10000G>A p.G3334R | Missense Mutation (SNP) | VAF 42/105 reads (40%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.998); catalogued as COSV100911449, COSV64241987; called by muse, varscan2
- FLNC | c.778G>A p.A260T | Missense Mutation (SNP) | VAF 6/31 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.468); catalogued as COSV57960355; called by muse, mutect2, varscan2
- FLOT2 | c.82G>A p.V28M | Missense Mutation (SNP) | VAF 10/25 reads (40%) | SIFT deleterious (0.02); PolyPhen benign (0.378); catalogued as rs376080270; called by muse, mutect2, varscan2
- FLT4 | c.1088del p.P363Rfs*27 | Frame Shift Del (DEL) | VAF 6/11 reads (55%) | catalogued as COSV99985814; called by mutect2, varscan2
- FMR1 | c.990+2T>C p.X330_splice | Splice Site (SNP) | VAF 110/132 reads (83%) | catalogued as COSV54422151; called by muse, mutect2, varscan2
- FOXD4L1 | c.676G>A p.A226T | Missense Mutation (SNP) | VAF 7/21 reads (33%) | SIFT tolerated (0.56); PolyPhen benign (0.034); catalogued as rs1487422588; called by muse, mutect2, varscan2
- FOXR1 | c.482G>A p.R161Q | Missense Mutation (SNP) | VAF 21/50 reads (42%) | SIFT tolerated (0.57); PolyPhen benign (0.007); catalogued as rs781949527, COSV57651407; called by muse, mutect2, varscan2
- FRYL | c.989del p.L330* | Frame Shift Del (DEL) | VAF 65/210 reads (31%) | catalogued as rs1348158626; called by mutect2, varscan2
- FSCB | c.440del p.P147Lfs*2 | Frame Shift Del (DEL) | VAF 46/162 reads (28%) | catalogued as COSV61219806; called by mutect2, pindel, varscan2
- FSTL4 | c.353C>T p.A118V | Missense Mutation (SNP) | VAF 21/51 reads (41%) | SIFT deleterious (0); PolyPhen possibly damaging (0.843); catalogued as COSV54764957; called by muse, mutect2, varscan2
- FSTL5 | c.1599del p.V534Lfs*5 | Frame Shift Del (DEL) | VAF 31/103 reads (30%) | catalogued as rs779560788, COSV60213555; called by mutect2, pindel, varscan2
- FUOM | c.184G>A p.V62M | Missense Mutation (SNP) | VAF 19/48 reads (40%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.976); catalogued as COSV53369283; called by muse, mutect2, varscan2
- GABBR1 | c.1721dup p.A575Sfs*2 | Frame Shift Ins (INS) | VAF 16/42 reads (38%) | catalogued as rs777471402; called by mutect2, varscan2
- GABBR1 | c.973G>A p.D325N | Missense Mutation (SNP) | VAF 13/29 reads (45%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.963); catalogued as rs1349895260, COSV63541130; called by muse, mutect2, varscan2
- GABRA1 | c.323T>C p.M108T | Missense Mutation (SNP) | VAF 12/59 reads (20%) | SIFT tolerated (0.2); PolyPhen benign (0.015); catalogued as COSV50099204; called by muse, varscan2
- GABRG1 | c.792dup p.D265* | Frame Shift Ins (INS) | VAF 52/175 reads (30%) | catalogued as rs772301203; called by mutect2, varscan2
- GALNT17 | c.514G>A p.V172M | Missense Mutation (SNP) | VAF 13/36 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); catalogued as rs773948542, COSV61149704; called by muse, mutect2, varscan2
- GATAD2B | c.125G>A p.R42H | Missense Mutation (SNP) | VAF 21/62 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as rs1347107092, COSV64083348; called by muse, mutect2, varscan2
- GBP5 | c.731del p.K244Sfs*13 | Frame Shift Del (DEL) | VAF 30/120 reads (25%) | catalogued as rs34148688; called by mutect2, varscan2
- GEMIN4 | c.112G>A p.D38N | Missense Mutation (SNP) | VAF 17/53 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as rs558697152, COSV57620041; called by muse, mutect2, varscan2
- GFRA1 | c.530del p.P177Rfs*68 | Frame Shift Del (DEL) | VAF 12/56 reads (21%) | catalogued as COSV62603532; called by mutect2, pindel, varscan2
- GGPS1 | c.25C>T p.Q9* | Nonsense Mutation (SNP) | VAF 25/54 reads (46%) | catalogued as COSV51396918; called by muse, mutect2, varscan2
- GGT1 | c.949G>A p.V317I | Missense Mutation (SNP) | VAF 88/246 reads (36%) | SIFT tolerated (0.43); PolyPhen benign (0.062); catalogued as rs757411384, COSV50638292; called by muse, mutect2, varscan2
- GIPC3 | c.685del p.A229Lfs*89 (on ENST00000644946; = p.A229Lfs*55 on NM_133261.3) | Frame Shift Del (DEL) | VAF 4/17 reads (24%) | catalogued as rs748150647, COSV99056389; called by mutect2, pindel, varscan2
- GIT1 | c.839C>T p.A280V | Missense Mutation (SNP) | VAF 17/50 reads (34%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.996); catalogued as COSV99838122; called by muse, mutect2, varscan2
- GLCCI1 | c.633G>T p.E211D | Missense Mutation (SNP) | VAF 9/25 reads (36%) | SIFT tolerated (0.16); PolyPhen probably damaging (0.98); catalogued as COSV99780295; called by muse, mutect2
- GLDC | c.286C>A p.P96T | Missense Mutation (SNP) | VAF 9/21 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV58676881; called by muse, mutect2, varscan2
- GLI3 | c.4741T>C p.*1581Qext*28 | Nonstop Mutation (SNP) | VAF 19/72 reads (26%) | catalogued as COSV67885688; called by muse, mutect2, varscan2
- GLI3 | c.4624C>T p.R1542W | Missense Mutation (SNP) | VAF 35/100 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.915); catalogued as rs755022753, CD150069, COSV67885690; called by muse, mutect2, varscan2
- GNB3 | c.76G>A p.A26T | Missense Mutation (SNP) | VAF 11/37 reads (30%) | SIFT tolerated (0.59); PolyPhen benign (0.034); catalogued as COSV51831322; called by muse, mutect2, varscan2
- GNGT1 | c.208G>T p.G70C | Missense Mutation (SNP) | VAF 24/73 reads (33%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.963); catalogued as COSV50352372; called by muse, mutect2, varscan2
- GNPTAB | c.3364G>A p.A1122T | Missense Mutation (SNP) | VAF 17/52 reads (33%) | SIFT deleterious (0.04); PolyPhen benign (0.35); catalogued as rs774443381, COSV54777271; called by muse, mutect2, varscan2
- GORASP1 | c.199G>A p.V67M | Missense Mutation (SNP) | VAF 30/101 reads (30%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.673); catalogued as rs1381414950, COSV57183364; called by muse, mutect2, varscan2
- GPAT3 | c.818G>A p.R273H | Missense Mutation (SNP) | VAF 29/69 reads (42%) | SIFT deleterious (0); PolyPhen benign (0.011); catalogued as rs771440613, COSV52355583; called by muse, varscan2
- GREB1 | c.4906G>T p.D1636Y | Missense Mutation (SNP) | VAF 14/50 reads (28%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.771); catalogued as COSV52181785; called by muse, mutect2, varscan2
- GRIA2 | c.857del p.P286Lfs*14 | Frame Shift Del (DEL) | VAF 22/83 reads (27%) | catalogued as COSV99645141; called by mutect2, pindel, varscan2
- GRM5 | c.2011A>G p.R671G | Missense Mutation (SNP) | VAF 44/161 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV59593161; called by muse, mutect2, varscan2
- GRM6 | c.2564A>G p.K855R | Missense Mutation (SNP) | VAF 19/54 reads (35%) | SIFT tolerated (0.28); PolyPhen benign (0.133); catalogued as COSV51435095; called by muse, mutect2, varscan2
- GSDMA | c.160G>A p.V54I | Missense Mutation (SNP) | VAF 6/23 reads (26%) | SIFT tolerated (0.68); PolyPhen benign (0.01); catalogued as rs533792064, COSV56980409; called by muse, mutect2, varscan2
- GTPBP3 | c.479G>A p.G160E | Missense Mutation (SNP) | VAF 7/25 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1490296182, COSV50173593; called by muse, mutect2, varscan2
- GYPB | c.257G>A p.R86H | Missense Mutation (SNP) | VAF 63/213 reads (30%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.603); catalogued as rs370247798; called by muse, mutect2, varscan2
- GYS1 | c.908G>A p.R303Q | Missense Mutation (SNP) | VAF 9/31 reads (29%) | SIFT deleterious (0.04); PolyPhen benign (0.031); catalogued as rs756642679, COSV54401543; called by muse, mutect2, varscan2
- HACE1 | c.2021C>A p.P674H | Missense Mutation (SNP) | VAF 16/51 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV53499596; called by muse, mutect2, varscan2
- HAP1 | c.1313A>T p.E438V | Missense Mutation (SNP) | VAF 12/38 reads (32%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.969); catalogued as COSV100169612; called by muse, mutect2
- HDAC5 | c.2793dup p.I932Hfs*24 | Frame Shift Ins (INS) | VAF 6/19 reads (32%) | catalogued as rs770174487; called by mutect2, varscan2
- HDLBP | c.3289-3del | Splice Region (DEL) | VAF 18/68 reads (26%) | catalogued as rs778255938; called by mutect2, pindel, varscan2
- HEATR5B | c.3073C>T p.R1025C | Missense Mutation (SNP) | VAF 12/57 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs267599367, COSV51848925; called by muse, mutect2, varscan2
- HELZ2 | c.2522C>T p.A841V (on ENST00000467148 / NM_001037335.2; = p.A272V on NM_033405.3) | Missense Mutation (SNP) | VAF 17/39 reads (44%) | SIFT tolerated (0.37); PolyPhen benign (0.31); catalogued as COSV64409146; called by muse, mutect2, varscan2
- HERC1 | c.8965G>A p.V2989I | Missense Mutation (SNP) | VAF 43/81 reads (53%) | SIFT tolerated (0.42); PolyPhen benign (0.011); catalogued as rs774657002, COSV71246226; called by muse, mutect2, varscan2
- HERC2 | c.11675C>T p.P3892L | Missense Mutation (SNP) | VAF 34/98 reads (35%) | SIFT tolerated (0.11); PolyPhen benign (0.001); catalogued as rs1451772766, COSV55309986, COSV99869767; called by muse, mutect2, varscan2
- HESX1 | c.17A>G p.Q6R | Missense Mutation (SNP) | VAF 20/41 reads (49%) | SIFT tolerated (0.21); PolyPhen benign (0); catalogued as COSV99907706; called by muse, mutect2, varscan2
- HIRA | c.2623C>T p.P875S | Missense Mutation (SNP) | VAF 7/25 reads (28%) | SIFT tolerated (0.39); PolyPhen benign (0.038); catalogued as COSV54272625; called by muse, mutect2, varscan2
- HIVEP1 | c.5915C>T p.A1972V | Missense Mutation (SNP) | VAF 30/78 reads (38%) | SIFT tolerated (0.06); PolyPhen benign (0.127); catalogued as rs761387327, COSV65099124; called by muse, mutect2, varscan2
- HJV | c.838T>A p.Y280N (on ENST00000336751 / NM_213653.4; = p.Y167N on NM_145277.5) | Missense Mutation (SNP) | VAF 8/22 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.939); catalogued as COSV60951304; called by muse, mutect2, varscan2
- HJV | c.431C>T p.A144V (on ENST00000336751 / NM_213653.4; = p.A31V on NM_145277.5) | Missense Mutation (SNP) | VAF 11/29 reads (38%) | SIFT tolerated (0.12); PolyPhen benign (0.003); catalogued as rs937971318, COSV60951289; called by muse, mutect2, varscan2
- HLA-A | c.74-1G>T p.X25_splice | Splice Site (SNP) | VAF 13/33 reads (39%) | catalogued as COSV65137942, COSV65145287; called by muse, mutect2, varscan2
- HLA-C | c.343+2T>C p.X115_splice | Splice Site (SNP) | VAF 14/57 reads (25%) | catalogued as COSV66111187; called by muse, mutect2, varscan2
- HLA-C | c.237G>T p.E79D | Missense Mutation (SNP) | VAF 28/98 reads (29%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.626); catalogued as COSV66111192; called by muse, mutect2, varscan2
- HMCN1 | c.16567A>G p.N5523D | Missense Mutation (SNP) | VAF 18/76 reads (24%) | SIFT deleterious (0.02); PolyPhen benign (0.355); catalogued as COSV54880909; called by muse, mutect2, varscan2
- HNMT | c.577G>T p.D193Y | Missense Mutation (SNP) | VAF 40/101 reads (40%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.867); catalogued as COSV54506572, COSV54506703; called by muse, mutect2, varscan2
- HNRNPA2B1 | c.7-3dup | Splice Region (INS) | VAF 10/59 reads (17%) | catalogued as rs759915055; called by pindel, varscan2
- HNRNPUL1 | c.2162G>A p.R721Q | Missense Mutation (SNP) | VAF 19/58 reads (33%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0); catalogued as rs532169618, COSV54560369; called by muse, mutect2, varscan2
- HOXC10 | c.71G>A p.R24H | Missense Mutation (SNP) | VAF 14/37 reads (38%) | SIFT tolerated (0.09); PolyPhen benign (0.099); catalogued as rs375878835, COSV57725828; called by muse, mutect2, varscan2
- HPSE | c.1055C>T p.A352V | Missense Mutation (SNP) | VAF 12/40 reads (30%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.993); catalogued as COSV60985640; called by muse, mutect2, varscan2
- HR | c.1219C>T p.R407W | Missense Mutation (SNP) | VAF 14/75 reads (19%) | SIFT deleterious (0.03); PolyPhen benign (0.153); catalogued as rs202057113, COSV57190935, COSV57191607; called by muse, mutect2, varscan2
- HSPG2 | c.8163C>T p.S2721= | Splice Region (SNP) | VAF 10/32 reads (31%) | catalogued as rs768337273, COSV65969417; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- IBSP | c.769G>A p.V257I | Missense Mutation (SNP) | VAF 20/51 reads (39%) | SIFT tolerated (0.09); PolyPhen benign (0.045); catalogued as rs758115196, COSV56894829; called by muse, mutect2, varscan2
- IDH3A | c.557A>G p.Y186C | Missense Mutation (SNP) | VAF 8/24 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1303775777, COSV55112149; called by muse, mutect2, varscan2
- IDH3A | c.860A>G p.E287G | Missense Mutation (SNP) | VAF 6/30 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99357277; called by muse, mutect2, varscan2
- IGF2R | c.3052T>G p.F1018V | Missense Mutation (SNP) | VAF 13/46 reads (28%) | SIFT tolerated (0.14); PolyPhen benign (0.259); catalogued as COSV100807220; called by muse, mutect2, varscan2
- INPP5B | c.1421T>C p.I474T (on ENST00000373023; = p.I394T on NM_005540.3 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 31/93 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.959); catalogued as COSV65959602; called by muse, mutect2, varscan2
- INPP5B | c.43del p.E15Nfs*58 | Frame Shift Del (DEL) | VAF 9/26 reads (35%) | catalogued as COSV65958400; called by mutect2, pindel, varscan2
- IPO7 | c.2173-2A>G p.X725_splice | Splice Site (SNP) | VAF 22/79 reads (28%) | catalogued as COSV65684324; called by muse, mutect2, varscan2
- IQCF2 | c.178C>T p.R60C | Missense Mutation (SNP) | VAF 13/27 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as rs370049735; called by muse, mutect2, varscan2
- IRX5 | c.628A>G p.K210E | Missense Mutation (SNP) | VAF 18/96 reads (19%) | SIFT tolerated (0.66); PolyPhen possibly damaging (0.677); catalogued as COSV58058494; called by muse, varscan2
- ITFG1 | c.1364G>A p.R455H | Missense Mutation (SNP) | VAF 76/235 reads (32%) | SIFT tolerated (0.17); PolyPhen benign (0.003); catalogued as rs766871022, COSV57744631, COSV57751781; called by muse, mutect2, varscan2
- ITGA5 | c.101C>T p.P34L | Missense Mutation (SNP) | VAF 12/42 reads (29%) | SIFT tolerated (0.69); PolyPhen benign (0); catalogued as rs756815283, COSV53216035; called by muse, mutect2
- ITGA9 | c.311G>A p.R104Q | Missense Mutation (SNP) | VAF 12/37 reads (32%) | SIFT tolerated (0.28); PolyPhen possibly damaging (0.862); catalogued as rs775282230, COSV53236995; called by muse, mutect2, varscan2
- ITGAV | c.3053T>C p.M1018T | Missense Mutation (SNP) | VAF 17/63 reads (27%) | SIFT deleterious (0.01); PolyPhen benign (0.089); catalogued as COSV53709621; called by muse, mutect2, varscan2
- ITGB6 | c.1820del p.P607Lfs*45 | Frame Shift Del (DEL) | VAF 26/95 reads (27%) | catalogued as COSV99324072; called by mutect2, pindel, varscan2
- ITIH1 | c.1232C>T p.T411M | Missense Mutation (SNP) | VAF 9/24 reads (38%) | SIFT deleterious (0.01); PolyPhen benign (0.223); catalogued as rs751754880, COSV56252465; called by muse, mutect2, varscan2
- ITPR2 | c.2873C>A p.P958H | Missense Mutation (SNP) | VAF 11/47 reads (23%) | SIFT tolerated (0.15); PolyPhen benign (0.139); catalogued as COSV67265582; called by muse, mutect2, varscan2
- ITSN1 | c.472dup p.L158Pfs*3 | Frame Shift Ins (INS) | VAF 20/60 reads (33%) | catalogued as rs751926247; called by mutect2, varscan2
- JPH2 | c.1129G>A p.A377T | Missense Mutation (SNP) | VAF 13/37 reads (35%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.572); catalogued as rs774653018, COSV100881576, COSV65901973; called by muse, mutect2, varscan2
- JPH2 | c.162G>A p.W54* | Nonsense Mutation (SNP) | VAF 11/27 reads (41%) | catalogued as rs769659929, COSV60696407; called by muse, mutect2, varscan2
- JRKL | c.452C>T p.A151V | Missense Mutation (SNP) | VAF 16/45 reads (36%) | SIFT deleterious (0.04); PolyPhen benign (0.005); catalogued as rs754087245, COSV53592193; called by muse, mutect2, varscan2
- KCNA4 | c.1286del p.G429Vfs*53 | Frame Shift Del (DEL) | VAF 8/26 reads (31%) | catalogued as rs1258313537; called by mutect2, pindel
- KCNC3 | c.2099G>A p.R700H | Missense Mutation (SNP) | VAF 18/54 reads (33%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.964); catalogued as rs758667095, COSV65386792; called by muse, varscan2
- KCNIP1 | c.551A>G p.Q184R (on ENST00000411494 / NM_001034837.3; = p.Q173R on NM_014592.4) | Missense Mutation (SNP) | VAF 20/55 reads (36%) | SIFT deleterious (0); PolyPhen benign (0.024); catalogued as COSV61080898; called by muse, mutect2, varscan2
- KCTD14 | c.115G>A p.V39I | Missense Mutation (SNP) | VAF 13/35 reads (37%) | SIFT tolerated (0.24); PolyPhen possibly damaging (0.636); catalogued as rs752112333, COSV62001096, COSV99074518; called by muse, mutect2, varscan2
- KDM5B | c.1370G>A p.S457N | Missense Mutation (SNP) | VAF 18/45 reads (40%) | SIFT deleterious (0); PolyPhen possibly damaging (0.678); catalogued as COSV52504870; called by muse, mutect2, varscan2
- KIAA0753 | c.1988T>C p.M663T | Missense Mutation (SNP) | VAF 31/102 reads (30%) | SIFT deleterious (0.02); PolyPhen benign (0.051); catalogued as COSV63816866; called by muse, mutect2, varscan2
- KIAA1549L | c.895A>G p.N299D (on ENST00000321505; = p.N596D on NM_012194.3) | Missense Mutation (SNP) | VAF 22/59 reads (37%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0.018); catalogued as rs754927908, COSV55770169; called by muse, mutect2, varscan2
- KIAA1755 | c.3113G>A p.R1038Q | Missense Mutation (SNP) | VAF 12/22 reads (55%) | SIFT tolerated (0.63); PolyPhen benign (0.003); catalogued as rs775747625, COSV54074255; called by muse, mutect2, varscan2
- KIF13A | c.3345dup p.V1116Sfs*4 | Frame Shift Ins (INS) | VAF 30/87 reads (34%) | catalogued as rs1346755993; called by mutect2, varscan2
- KIF13A | c.2566G>A p.V856I | Missense Mutation (SNP) | VAF 20/73 reads (27%) | SIFT tolerated (0.52); PolyPhen benign (0); catalogued as rs547042809, COSV52442068; called by muse, mutect2, varscan2
- KIF26B | c.748G>A p.A250T | Missense Mutation (SNP) | VAF 19/55 reads (35%) | SIFT tolerated (0.2); PolyPhen benign (0.005); catalogued as rs371419440; called by muse, mutect2, varscan2
- KIF4B | c.1792C>T p.R598C | Missense Mutation (SNP) | VAF 48/150 reads (32%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.99); catalogued as rs771863736, COSV70528098; called by muse, mutect2, varscan2
- KIFC1 | c.1600C>T p.R534W | Missense Mutation (SNP) | VAF 21/62 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.959); catalogued as rs373384743; called by muse, mutect2, varscan2
- KLF16 | c.748G>A p.A250T | Missense Mutation (SNP) | VAF 4/14 reads (29%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.034); catalogued as rs775035830; called by muse, mutect2
- KLHDC8A | c.383G>A p.R128Q | Missense Mutation (SNP) | VAF 14/28 reads (50%) | SIFT tolerated (0.17); PolyPhen benign (0.09); catalogued as rs1327258142, COSV65678288; called by muse, mutect2, varscan2
- KLHL20 | c.932G>A p.R311Q | Missense Mutation (SNP) | VAF 28/70 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as COSV52940497; called by muse, mutect2, varscan2
- KLKB1 | c.1578G>T p.K526N | Missense Mutation (SNP) | VAF 45/108 reads (42%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.824); catalogued as rs748884850, COSV52994217; called by muse, mutect2, varscan2
- KMT2C | c.9841A>G p.M3281V | Missense Mutation (SNP) | VAF 49/159 reads (31%) | SIFT tolerated (0.13); PolyPhen benign (0.006); catalogued as COSV51339090; called by muse, mutect2, varscan2
- KMT2D | c.8183C>T p.A2728V | Missense Mutation (SNP) | VAF 6/29 reads (21%) | SIFT deleterious (0.03); PolyPhen benign (0.054); catalogued as COSV99980099; called by muse, mutect2
- KRT17 | c.349C>T p.R117C | Missense Mutation (SNP) | VAF 41/109 reads (38%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.969); catalogued as rs375507162; called by muse, mutect2, varscan2
- KRT17 | c.65del p.G22Afs*93 | Frame Shift Del (DEL) | VAF 12/37 reads (32%) | catalogued as rs753167272; called by mutect2, pindel, varscan2
- KRT33A | c.719G>A p.R240H | Missense Mutation (SNP) | VAF 20/44 reads (45%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.458); catalogued as rs151076240, COSV50365676; called by muse, mutect2, varscan2
- KRT82 | c.643C>T p.R215C | Missense Mutation (SNP) | VAF 12/29 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs368818089; called by muse, mutect2, varscan2
- KSR1 | c.523G>T p.G175W (on ENST00000644974 / NM_001367810.1; = p.G38W on NM_014238.2) | Missense Mutation (SNP) | VAF 18/56 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.942); catalogued as COSV52028857; called by muse, mutect2, varscan2
- KY | c.697G>A p.E233K | Missense Mutation (SNP) | VAF 23/69 reads (33%) | SIFT tolerated (0.22); PolyPhen possibly damaging (0.907); catalogued as rs770241529, COSV71016590; called by muse, mutect2, varscan2
- L3MBTL4 | c.1809G>A p.M603I | Missense Mutation (SNP) | VAF 34/84 reads (40%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.999); catalogued as COSV53114543; called by muse, mutect2, varscan2
- LAMB1 | c.3277G>A p.G1093R | Missense Mutation (SNP) | VAF 40/91 reads (44%) | SIFT tolerated (0.25); PolyPhen benign (0.167); catalogued as rs560469042, COSV55962120; called by muse, mutect2, varscan2
- LAMB2 | c.1004C>T p.P335L | Missense Mutation (SNP) | VAF 27/58 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs572263570, COSV59731278; called by muse, mutect2, varscan2
- LANCL2 | c.740G>A p.R247H | Missense Mutation (SNP) | VAF 26/77 reads (34%) | SIFT tolerated (0.09); PolyPhen benign (0.022); catalogued as rs761840899, COSV99634702; called by muse, mutect2, varscan2
- LARP1B | c.2257del p.M753Cfs*21 | Frame Shift Del (DEL) | VAF 76/216 reads (35%) | catalogued as rs1311334991; called by mutect2, pindel, varscan2
- LCMT2 | c.400G>A p.A134T | Missense Mutation (SNP) | VAF 5/16 reads (31%) | SIFT tolerated (0.33); PolyPhen benign (0.015); catalogued as rs772239826; called by muse, mutect2, varscan2
- LHFPL4 | c.331A>G p.T111A | Missense Mutation (SNP) | VAF 8/31 reads (26%) | SIFT tolerated (0.66); PolyPhen benign (0.012); catalogued as COSV99805399; called by muse, mutect2, varscan2
- LIG3 | c.2018G>T p.W673L | Missense Mutation (SNP) | VAF 23/56 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV52006051; called by muse, mutect2, varscan2
- LIMCH1 | c.2414del p.K805Rfs*20 | Frame Shift Del (DEL) | VAF 81/263 reads (31%) | catalogued as rs773592947, COSV58296104; called by mutect2, pindel, varscan2
- LONRF3 | c.920G>A p.R307H | Missense Mutation (SNP) | VAF 22/36 reads (61%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.738); catalogued as rs749076984, COSV59150281; called by muse, mutect2, varscan2
- LRP2 | c.10145C>A p.A3382E | Missense Mutation (SNP) | VAF 20/45 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.909); catalogued as COSV55543041, COSV55552382; called by muse, mutect2, varscan2
- LRRC49 | c.635del p.L212* | Frame Shift Del (DEL) | VAF 34/92 reads (37%) | catalogued as rs750986316; called by mutect2, pindel, varscan2
- LRRIQ3 | c.414del p.G139Dfs*20 | Frame Shift Del (DEL) | VAF 15/53 reads (28%) | catalogued as rs749244073; called by mutect2, pindel, varscan2
- LURAP1 | c.166G>A p.G56R | Missense Mutation (SNP) | VAF 7/26 reads (27%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.992); catalogued as COSV64338006; called by muse, mutect2, varscan2
- LZTS1 | c.977G>A p.R326H | Missense Mutation (SNP) | VAF 12/44 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.959); catalogued as rs200864732, COSV56115949; called by muse, mutect2, varscan2
- MACF1 | c.7748A>G p.Q2583R | Missense Mutation (SNP) | VAF 32/79 reads (41%) | catalogued as COSV99243355; called by muse, mutect2, varscan2
- MAD2L1BP | c.304_306del p.S102del | In Frame Del (DEL) | VAF 16/47 reads (34%) | catalogued as rs1436883374; called by mutect2, pindel, varscan2
- MAGEB2 | c.1A>G p.M1? | Translation Start Site (SNP) | VAF 50/73 reads (68%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.993); catalogued as rs750718375, COSV66780282; called by muse, mutect2, varscan2
- MAGI1 | c.2778A>C p.E926D (on ENST00000402939 / NM_001033057.2; = p.E954D on NM_004742.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 17/46 reads (37%) | SIFT tolerated (0.07); PolyPhen benign (0.431); catalogued as COSV100440378; called by muse, mutect2
- MAP1B | c.5690G>A p.R1897Q | Missense Mutation (SNP) | VAF 10/41 reads (24%) | SIFT tolerated (0.09); PolyPhen benign (0.007); catalogued as rs781044243, COSV57094491; called by muse, mutect2, varscan2
- MAP3K10 | c.1381C>T p.R461C | Missense Mutation (SNP) | VAF 15/34 reads (44%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.899); catalogued as rs534097924, COSV53420690; called by muse, mutect2, varscan2
- MAP3K4 | c.3547G>A p.A1183T | Missense Mutation (SNP) | VAF 8/22 reads (36%) | SIFT tolerated (0.57); PolyPhen benign (0); catalogued as rs367611856; called by muse, mutect2, varscan2
- MAPKAPK3 | c.541G>A p.A181T | Missense Mutation (SNP) | VAF 27/65 reads (42%) | SIFT tolerated (0.11); PolyPhen benign (0.014); catalogued as rs372421280, COSV63596905; called by muse, mutect2, varscan2
- MARCHF4 | c.167G>A p.R56H | Missense Mutation (SNP) | VAF 30/72 reads (42%) | SIFT tolerated, low confidence (0.05); PolyPhen possibly damaging (0.828); catalogued as COSV56103180; called by muse, mutect2, varscan2
- MAST2 | c.2257C>T p.P753S | Missense Mutation (SNP) | VAF 21/50 reads (42%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.309); catalogued as COSV63616356; called by muse, mutect2, varscan2
- MAVS | c.1459G>A p.A487T | Missense Mutation (SNP) | VAF 5/14 reads (36%) | SIFT tolerated (0.27); PolyPhen benign (0.034); catalogued as COSV63926511; called by muse, mutect2, varscan2
- MBD6 | c.2345del p.G782Efs*13 | Frame Shift Del (DEL) | VAF 14/35 reads (40%) | catalogued as rs746267361; called by mutect2, varscan2
- MBOAT7 | c.800C>A p.A267D | Missense Mutation (SNP) | VAF 5/11 reads (45%) | SIFT tolerated (0.6); PolyPhen benign (0.013); catalogued as COSV55474541; called by muse, mutect2, varscan2
- MCM4 | c.1826C>T p.A609V | Missense Mutation (SNP) | VAF 23/61 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs1374301498, COSV50621490; called by muse, mutect2, varscan2
- MDN1 | c.407T>C p.V136A | Missense Mutation (SNP) | VAF 19/65 reads (29%) | SIFT deleterious (0.03); PolyPhen benign (0.053); catalogued as COSV65517943; called by muse, mutect2, varscan2
- MED25 | c.1681G>A p.G561R | Missense Mutation (SNP) | VAF 3/33 reads (9%) | SIFT deleterious (0.03); PolyPhen benign (0.211); catalogued as rs1276513854; called by muse, mutect2
- MED7 | c.412A>G p.M138V | Missense Mutation (SNP) | VAF 35/93 reads (38%) | SIFT tolerated (0.05); PolyPhen benign (0.084); catalogued as rs1252329617, COSV53849767; called by muse, mutect2, varscan2
- MEGF6 | c.3046G>A p.G1016R | Missense Mutation (SNP) | VAF 12/44 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs189364002; called by muse, mutect2, varscan2
- MEGF8 | c.5096C>T p.A1699V (on ENST00000251268 / NM_001271938.2; = p.A1632V on NM_001410.3) | Missense Mutation (SNP) | VAF 7/25 reads (28%) | SIFT tolerated (1); PolyPhen benign (0.017); catalogued as rs745965273, COSV52076663; called by muse, mutect2, varscan2
- MEI1 | c.101G>A p.R34H | Missense Mutation (SNP) | VAF 15/30 reads (50%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.46); catalogued as COSV55901185; called by muse, mutect2, varscan2
- MFGE8 | c.605C>T p.A202V | Missense Mutation (SNP) | VAF 23/36 reads (64%) | SIFT tolerated (0.14); PolyPhen benign (0.013); catalogued as COSV51555285; called by muse, mutect2, varscan2
- MFSD9 | c.1326del p.S443Afs*6 | Frame Shift Del (DEL) | VAF 11/48 reads (23%) | catalogued as rs769987847; called by mutect2, pindel, varscan2
- MICAL1 | c.132dup p.L45Afs*97 | Frame Shift Ins (INS) | VAF 10/39 reads (26%) | catalogued as rs922604988; called by mutect2, pindel, varscan2
- MICAL3 | c.4495del p.R1499Gfs*106 | Frame Shift Del (DEL) | VAF 15/41 reads (37%) | catalogued as rs765803753; called by mutect2, pindel, varscan2
- MIDEAS | c.526G>T p.D176Y | Missense Mutation (SNP) | VAF 12/36 reads (33%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.804); catalogued as COSV54093075; called by muse, mutect2, varscan2
- MMP9 | c.265G>A p.A89T | Missense Mutation (SNP) | VAF 14/40 reads (35%) | SIFT tolerated (0.89); PolyPhen benign (0); catalogued as rs1250570940, COSV64884291; called by muse, mutect2, varscan2
- MON1B | c.611C>T p.A204V | Missense Mutation (SNP) | VAF 10/35 reads (29%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.878); catalogued as COSV50245502; called by muse, mutect2, varscan2
- MORC2 | c.716C>T p.S239L (on ENST00000397641 / NM_001303256.3; = p.S177L on NM_014941.3) | Missense Mutation (SNP) | VAF 3/14 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs1387852860, COSV99309326; called by muse, mutect2
- MPP4 | c.611A>G p.N204S | Missense Mutation (SNP) | VAF 9/33 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs760255426, COSV59629336; called by muse, mutect2, varscan2
- MRPL17 | c.138G>T p.W46C | Missense Mutation (SNP) | VAF 15/47 reads (32%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.932); catalogued as rs774823017, COSV56618180; called by muse, mutect2, varscan2
- MRPS11 | c.183C>T p.S61= | Splice Region (SNP) | VAF 32/84 reads (38%) | catalogued as COSV57914712; called by muse, mutect2, varscan2
- MRPS2 | c.293G>A p.R98Q | Missense Mutation (SNP) | VAF 9/16 reads (56%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.971); catalogued as rs746234639, COSV54092284, COSV99613722; called by muse, mutect2, varscan2
- MRPS30 | c.689G>A p.R230Q | Missense Mutation (SNP) | VAF 36/108 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs780785088, COSV50181523; called by muse, mutect2, varscan2
- MSL3 | c.277C>T p.R93C | Missense Mutation (SNP) | VAF 41/55 reads (75%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.99); catalogued as rs763773048, COSV56491832; called by muse, mutect2, varscan2
- MTARC1 | c.388T>G p.Y130D | Missense Mutation (SNP) | VAF 21/53 reads (40%) | SIFT tolerated (0.38); PolyPhen benign (0.003); catalogued as COSV65055262; called by muse, mutect2, varscan2
- MTF1 | c.2224G>A p.E742K | Missense Mutation (SNP) | VAF 23/61 reads (38%) | SIFT tolerated, low confidence (0.17); PolyPhen benign (0.035); catalogued as COSV65988475; called by muse, mutect2, varscan2
- MTMR7 | c.199G>A p.G67R | Missense Mutation (SNP) | VAF 36/112 reads (32%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs1267688718, COSV51663451; called by muse, mutect2, varscan2
- MTOR | c.5740G>T p.G1914C | Missense Mutation (SNP) | VAF 21/46 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100816577, COSV63868893; called by muse, mutect2, varscan2
- MTOR | c.4730C>T p.A1577V | Missense Mutation (SNP) | VAF 26/60 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as COSV63868896; called by muse, mutect2, varscan2
- MTUS2 | c.2723G>A p.R908Q | Missense Mutation (SNP) | VAF 12/45 reads (27%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.966); catalogued as rs542576593, COSV54984176, COSV99685789; called by muse, mutect2, varscan2
- MTX2 | c.381G>A p.L127= | Splice Region (SNP) | VAF 43/127 reads (34%) | catalogued as COSV50887492; called by muse, mutect2, varscan2
- MUC15 | c.282G>C p.E94D | Missense Mutation (SNP) | VAF 71/250 reads (28%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV55553002; called by muse, mutect2, varscan2
- MUC4 | c.15190G>T p.G5064W (on ENST00000463781 / NM_018406.7; = p.G828W on NM_004532.6) | Missense Mutation (SNP) | VAF 22/60 reads (37%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.759); catalogued as COSV100206762, COSV57769537; called by muse, mutect2, varscan2
- MUC5B | c.16982G>A p.R5661H | Missense Mutation (SNP) | VAF 15/65 reads (23%) | SIFT tolerated (0.54); PolyPhen benign (0.011); catalogued as rs759499108, COSV71590360; called by muse, mutect2, varscan2
- MYBL1 | c.1104T>C p.D368= | Splice Region (SNP) | VAF 15/75 reads (20%) | catalogued as COSV72918729; called by muse, mutect2, varscan2
- MYH14 | c.1421T>C p.L474P | Missense Mutation (SNP) | VAF 19/41 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV51811325; called by muse, mutect2, varscan2
- MYH3 | c.4222G>C p.V1408L | Missense Mutation (SNP) | VAF 15/70 reads (21%) | SIFT tolerated (0.12); PolyPhen benign (0.02); catalogued as COSV56861635; called by muse, mutect2, varscan2
- MYH6 | c.2202G>T p.E734D | Missense Mutation (SNP) | VAF 29/81 reads (36%) | SIFT tolerated (0.15); PolyPhen benign (0.007); catalogued as COSV62448242, COSV62454725; called by muse, mutect2, varscan2
- MYO15A | c.5483G>A p.R1828H | Missense Mutation (SNP) | VAF 10/21 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs199973505, COSV52752702; called by muse, mutect2, varscan2
- MYO1B | c.266A>G p.D89G | Missense Mutation (SNP) | VAF 12/28 reads (43%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.534); catalogued as COSV58427816; called by muse, mutect2, varscan2
- MYO9A | c.4123A>G p.S1375G | Missense Mutation (SNP) | VAF 23/58 reads (40%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.096); catalogued as COSV61848105; called by muse, mutect2, varscan2
- MYOM1 | c.2597del p.P866Rfs*31 | Frame Shift Del (DEL) | VAF 21/78 reads (27%) | catalogued as rs1567922056; called by mutect2, pindel, varscan2
- MYPOP | c.919C>T p.P307S | Missense Mutation (SNP) | VAF 3/11 reads (27%) | SIFT tolerated, low confidence (0.16); PolyPhen probably damaging (0.992); catalogued as rs1323833806; called by muse, mutect2
- N4BP2 | c.4975-2A>G p.X1659_splice | Splice Site (SNP) | VAF 25/84 reads (30%) | catalogued as COSV54699596; called by muse, mutect2, varscan2
- NBAS | c.7007A>G p.E2336G | Missense Mutation (SNP) | VAF 15/42 reads (36%) | SIFT tolerated (0.12); PolyPhen benign (0.003); catalogued as COSV55713925; called by muse, mutect2, varscan2
- NCAM2 | c.1952T>C p.I651T | Missense Mutation (SNP) | VAF 52/143 reads (36%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.982); catalogued as COSV53059160; called by muse, mutect2, varscan2
- NCKAP1L | c.213G>A p.T71= | Splice Region (SNP) | VAF 27/65 reads (42%) | catalogued as rs778692151, COSV53203896; called by muse, mutect2, varscan2
- NCS1 | c.196A>G p.T66A | Missense Mutation (SNP) | VAF 13/34 reads (38%) | SIFT tolerated (0.28); PolyPhen benign (0); catalogued as COSV64962132; called by muse, mutect2, varscan2
- NEDD9 | c.134T>C p.L45P | Missense Mutation (SNP) | VAF 35/82 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV65158539; called by muse, mutect2, varscan2
- NEIL1 | c.283C>T p.R95C | Missense Mutation (SNP) | VAF 7/26 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.718); catalogued as COSV61833127; called by muse, mutect2, varscan2
- NEU4 | c.239C>T p.A80V (on ENST00000391969 / NM_001167602.3; = p.A92V on NM_080741.4) | Missense Mutation (SNP) | VAF 14/41 reads (34%) | SIFT tolerated (0.08); PolyPhen benign (0.067); catalogued as rs780590587, COSV57989617; called by muse, mutect2, varscan2
- NF1 | c.4157del p.K1386Rfs*20 | Frame Shift Del (DEL) | VAF 15/54 reads (28%) | catalogued as rs1567859802; called by mutect2, pindel, varscan2
- NFASC | c.2168G>A p.S723N (on ENST00000339876 / NM_001378329.1; = p.S719N on NM_015090.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 15/32 reads (47%) | SIFT tolerated (0.83); PolyPhen benign (0.075); catalogued as rs1039481002, COSV58360087; called by muse, mutect2, varscan2
- NFASC | c.2816C>T p.A939V | Missense Mutation (SNP) | VAF 43/105 reads (41%) | SIFT tolerated (0.51); PolyPhen benign (0.003); catalogued as rs573424743, COSV58360105; called by muse, mutect2, varscan2
- NFKBIL1 | c.648G>T p.Q216H | Missense Mutation (SNP) | VAF 15/50 reads (30%) | SIFT tolerated (0.1); PolyPhen benign (0.435); catalogued as COSV65990182; called by muse, mutect2, varscan2
- NGLY1 | c.491C>T p.T164M | Missense Mutation (SNP) | VAF 70/177 reads (40%) | SIFT tolerated (0.39); PolyPhen benign (0.003); catalogued as rs749441809, COSV54984290; called by muse, mutect2, varscan2
- NHLH2 | c.302G>A p.R101H | Missense Mutation (SNP) | VAF 12/26 reads (46%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as rs867911589, COSV57201713; called by muse, mutect2, varscan2
- NHSL2 | c.1403G>T p.R468M (on ENST00000510661; = p.R834M on NM_001013627.2) | Missense Mutation (SNP) | VAF 35/48 reads (73%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs763896310, COSV65452519; called by muse, mutect2, varscan2
- NIBAN3 | c.1383G>A p.M461I | Missense Mutation (SNP) | VAF 14/43 reads (33%) | SIFT tolerated (0.49); PolyPhen benign (0.003); catalogued as COSV56305734; called by muse, mutect2, varscan2
- NIN | c.4673C>T p.T1558M (on ENST00000382041 / NM_182946.1; = p.T845M on NM_016350.4) | Missense Mutation (SNP) | VAF 36/117 reads (31%) | SIFT deleterious (0.01); PolyPhen benign (0.165); catalogued as rs776474311, COSV55381771; called by muse, mutect2, varscan2
- NLGN4X | c.1342C>A p.Q448K | Missense Mutation (SNP) | VAF 51/69 reads (74%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV52006362; called by muse, mutect2, varscan2
- NLK | c.472C>T p.P158S | Missense Mutation (SNP) | VAF 36/99 reads (36%) | SIFT tolerated (0.28); PolyPhen probably damaging (1); catalogued as COSV69407659; called by muse, mutect2, varscan2
- NLRP9 | c.2324G>T p.R775M | Missense Mutation (SNP) | VAF 7/21 reads (33%) | SIFT tolerated (0.05); PolyPhen benign (0.026); catalogued as COSV100242912; called by muse, mutect2, varscan2
- NLRX1 | c.218C>T p.A73V | Missense Mutation (SNP) | VAF 4/22 reads (18%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV52702002, COSV52704933; called by muse, mutect2
- NMRK1 | c.196dup p.M66Nfs*25 | Frame Shift Ins (INS) | VAF 18/73 reads (25%) | catalogued as rs763848389; called by pindel, varscan2
- NOP58 | c.1571dup p.R525Efs*35 | Frame Shift Ins (INS) | VAF 32/165 reads (19%) | catalogued as rs769985110; called by mutect2, varscan2
- NOS2 | c.2959G>A p.A987T | Missense Mutation (SNP) | VAF 30/71 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as COSV58222165; called by muse, mutect2, varscan2
- NOTCH1 | c.1039G>A p.G347S | Missense Mutation (SNP) | VAF 7/21 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs746187371, COSV53031159, COSV53032363; called by muse, mutect2, varscan2
- NOVA1 | c.101del p.P34Lfs*19 | Frame Shift Del (DEL) | VAF 4/26 reads (15%) | catalogued as rs765756993; called by mutect2, pindel
- NOXRED1 | c.307G>A p.A103T | Missense Mutation (SNP) | VAF 14/42 reads (33%) | SIFT tolerated (0.21); PolyPhen benign (0.066); catalogued as COSV100033296, COSV53627575; called by muse, mutect2, varscan2
- NPFFR2 | c.1372del p.R458Efs*10 | Frame Shift Del (DEL) | VAF 19/69 reads (28%) | catalogued as rs1405220543; called by mutect2, pindel, varscan2
- NPTX1 | c.1151G>A p.R384H | Missense Mutation (SNP) | VAF 12/32 reads (38%) | SIFT tolerated (0.34); PolyPhen probably damaging (0.999); catalogued as rs375690569; called by muse, mutect2, varscan2
- NRBF2 | c.392A>G p.Q131R | Missense Mutation (SNP) | VAF 48/128 reads (38%) | SIFT tolerated (0.56); PolyPhen benign (0.003); catalogued as COSV53258520; called by muse, mutect2, varscan2
- NRG3 | c.824-1G>T p.X275_splice | Splice Site (SNP) | VAF 12/38 reads (32%) | catalogued as COSV64547073; called by muse, mutect2, varscan2
- NTRK2 | c.40C>T p.R14W | Missense Mutation (SNP) | VAF 21/62 reads (34%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.613); catalogued as COSV52855501; called by muse, mutect2, varscan2
- NUDT17 | c.434A>G p.E145G | Missense Mutation (SNP) | VAF 10/30 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100492852; called by muse, mutect2, varscan2
- NUP50 | c.433C>T p.L145F | Missense Mutation (SNP) | VAF 16/152 reads (11%) | SIFT tolerated (0.58); PolyPhen benign (0); catalogued as rs371473562; called by muse, mutect2, varscan2
- OBSCN | c.20977del p.A6993Pfs*79 | Frame Shift Del (DEL) | VAF 23/47 reads (49%) | catalogued as rs762005098; called by mutect2, varscan2
- OLFM1 | c.692C>T p.T231M (on ENST00000371793 / NM_001282611.2; = p.T213M on NM_014279.5) | Missense Mutation (SNP) | VAF 8/16 reads (50%) | SIFT tolerated (0.39); PolyPhen probably damaging (0.999); catalogued as rs1274655533, COSV53276097, COSV53276873; called by muse, mutect2, varscan2
- OPA1 | c.32+1G>A p.X11_splice | Splice Site (SNP) | VAF 28/53 reads (53%) | catalogued as CS101678, COSV62479170; called by muse, mutect2, varscan2
- OPCML | c.218C>A p.T73N | Missense Mutation (SNP) | VAF 18/53 reads (34%) | SIFT tolerated (0.38); PolyPhen benign (0.041); catalogued as COSV59401704, COSV59423681; called by muse, mutect2, varscan2
- OR10G8 | c.26C>T p.A9V | Missense Mutation (SNP) | VAF 35/120 reads (29%) | SIFT tolerated (0.06); PolyPhen benign (0.001); catalogued as rs766936722, COSV70908207; called by muse, mutect2, varscan2
- OR2B2 | c.754del p.Y252Mfs*34 | Frame Shift Del (DEL) | VAF 23/80 reads (29%) | catalogued as rs1306053868; called by mutect2, pindel, varscan2
- OR2M3 | c.656C>T p.A219V | Missense Mutation (SNP) | VAF 74/231 reads (32%) | SIFT tolerated (0.13); PolyPhen benign (0.05); catalogued as COSV71758892, COSV71759096; called by muse, mutect2, varscan2
- OR2Y1 | c.232G>A p.V78M | Missense Mutation (SNP) | VAF 19/52 reads (37%) | SIFT deleterious (0.01); PolyPhen benign (0.341); catalogued as rs373477986; called by muse, mutect2, varscan2
- OR4D1 | c.373G>A p.A125T | Missense Mutation (SNP) | VAF 19/48 reads (40%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV52124573; called by muse, mutect2, varscan2
- OR51V1 | c.209C>T p.A70V | Missense Mutation (SNP) | VAF 5/55 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.791); catalogued as COSV58314264; called by muse, mutect2
- OR5K1 | c.365G>T p.R122L | Missense Mutation (SNP) | VAF 65/157 reads (41%) | SIFT deleterious (0); PolyPhen possibly damaging (0.749); catalogued as COSV60303652; called by muse, mutect2, varscan2
- OR6C1 | c.503G>T p.R168M | Missense Mutation (SNP) | VAF 89/248 reads (36%) | SIFT deleterious, low confidence (0.05); PolyPhen possibly damaging (0.537); catalogued as COSV65572753; called by muse, mutect2, varscan2
- OR6K2 | c.47C>A p.A16D | Missense Mutation (SNP) | VAF 9/25 reads (36%) | SIFT tolerated (0.11); PolyPhen benign (0.003); catalogued as COSV100656756, COSV62743152; called by muse, mutect2, varscan2
- OSCP1 | c.610G>T p.G204W (on ENST00000356637 / NM_001330493.1; = p.G194W on NM_145047.5) | Missense Mutation (SNP) | VAF 19/44 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.928); catalogued as COSV52485034; called by muse, mutect2, varscan2
- OSM | c.289C>T p.Q97* | Nonsense Mutation (SNP) | VAF 8/22 reads (36%) | catalogued as COSV53160842, COSV53161640; called by muse, mutect2, varscan2
- OSMR | c.1849del p.T617Qfs*20 | Frame Shift Del (DEL) | VAF 15/50 reads (30%) | catalogued as rs762315064; called by mutect2, pindel, varscan2
- OTOF | c.1570G>A p.G524R | Missense Mutation (SNP) | VAF 11/36 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs146739635; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- OTOP3 | c.565G>A p.G189S | Missense Mutation (SNP) | VAF 11/34 reads (32%) | SIFT tolerated (0.17); PolyPhen benign (0.012); catalogued as rs1338831129, COSV60912452; called by muse, mutect2, varscan2
- OTX2 | c.106del p.R36Gfs*15 (on ENST00000408990 / NM_172337.3; = p.R44Gfs*15 on NM_021728.4) | Frame Shift Del (DEL) | VAF 5/32 reads (16%) | catalogued as CD124838, COSV100258088; called by mutect2, pindel
- P2RX6 | c.1160T>C p.V387A | Missense Mutation (SNP) | VAF 11/37 reads (30%) | SIFT tolerated (0.72); PolyPhen benign (0); catalogued as COSV60382597; called by muse, mutect2, varscan2
- PAFAH1B2 | c.190del p.S64Pfs*6 | Frame Shift Del (DEL) | VAF 9/34 reads (26%) | catalogued as COSV100505960, COSV59166701; called by mutect2, pindel, varscan2
- PAPPA2 | c.5347C>T p.R1783W | Missense Mutation (SNP) | VAF 39/74 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV62791699; called by muse, mutect2, varscan2
- PAQR6 | c.118_120del p.L40del | In Frame Del (DEL) | VAF 12/34 reads (35%) | catalogued as rs761428170; called by mutect2, pindel, varscan2
- PARP14 | c.3187G>A p.D1063N | Missense Mutation (SNP) | VAF 35/100 reads (35%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as rs751235147, COSV71734192; called by muse, mutect2, varscan2
- PARP4 | c.2645A>G p.D882G | Missense Mutation (SNP) | VAF 18/42 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV67960761; called by muse, mutect2, varscan2
- PBRM1 | c.1700A>T p.D567V | Missense Mutation (SNP) | VAF 20/63 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56263285, COSV99968660; called by muse, mutect2, varscan2
- PC | c.1796G>A p.S599N | Missense Mutation (SNP) | VAF 14/40 reads (35%) | SIFT tolerated (0.62); PolyPhen benign (0); catalogued as COSV67367912; called by muse, mutect2, varscan2
- PCDH12 | c.2623C>T p.P875S | Missense Mutation (SNP) | VAF 12/45 reads (27%) | SIFT tolerated (0.24); PolyPhen benign (0.04); catalogued as COSV51519681; called by muse, mutect2, varscan2
- PCDH12 | c.1756G>T p.G586C | Missense Mutation (SNP) | VAF 9/29 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV51519695; called by muse, mutect2, varscan2
- PCDHA12 | c.1217C>T p.S406L | Missense Mutation (SNP) | VAF 48/133 reads (36%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.996); catalogued as COSV56475827; called by muse, mutect2, varscan2
- PCDHA13 | c.1510C>A p.L504M | Missense Mutation (SNP) | VAF 46/91 reads (51%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.936); catalogued as COSV56480970; called by muse, mutect2, varscan2
- PCDHA2 | c.1489C>T p.R497W | Missense Mutation (SNP) | VAF 35/94 reads (37%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.986); catalogued as COSV65365163; called by muse, mutect2, varscan2
- PCDHA3 | c.1103T>C p.V368A | Missense Mutation (SNP) | VAF 30/86 reads (35%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.987); catalogued as rs373674603; called by muse, mutect2, varscan2
- PCDHB4 | c.586G>A p.D196N | Missense Mutation (SNP) | VAF 27/65 reads (42%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.232); catalogued as rs372815960; called by muse, mutect2, varscan2
- PCDHB7 | c.616C>A p.P206T | Missense Mutation (SNP) | VAF 16/63 reads (25%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.41); catalogued as COSV50755298; called by muse, mutect2, varscan2
- PCDHGA2 | c.1593G>T p.W531C | Missense Mutation (SNP) | VAF 22/84 reads (26%) | SIFT tolerated, low confidence (0.18); PolyPhen benign (0.021); catalogued as COSV53906786; called by muse, mutect2, varscan2
- PCDHGA4 | c.619G>A p.G207S | Missense Mutation (SNP) | VAF 18/45 reads (40%) | SIFT tolerated, low confidence (0.96); PolyPhen benign (0.022); catalogued as rs771155381, COSV53893250; called by muse, mutect2, varscan2
- PCDHGC3 | c.757G>A p.V253I | Missense Mutation (SNP) | VAF 4/16 reads (25%) | SIFT tolerated (0.27); PolyPhen possibly damaging (0.637); catalogued as COSV52744953; called by muse, mutect2
- PCLO | c.11221A>G p.S3741G | Missense Mutation (SNP) | VAF 54/142 reads (38%) | SIFT tolerated (0.1); PolyPhen benign (0.009); catalogued as rs751099661, COSV61618600; called by muse, mutect2, varscan2
- PCNT | c.7331C>T p.T2444I | Missense Mutation (SNP) | VAF 7/26 reads (27%) | SIFT deleterious (0.05); PolyPhen benign (0.047); catalogued as COSV100855358; called by muse, mutect2, varscan2
- PCSK5 | c.808G>A p.A270T | Missense Mutation (SNP) | VAF 18/50 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV65090873; called by muse, mutect2, varscan2
- PDE7A | c.1179del p.K393Nfs*6 (on ENST00000401827 / NM_001242318.3; = p.K367Nfs*6 on NM_002603.4) | Frame Shift Del (DEL) | VAF 19/59 reads (32%) | catalogued as rs776556726; called by mutect2, varscan2
- PDE7B | c.424C>T p.H142Y | Missense Mutation (SNP) | VAF 11/28 reads (39%) | SIFT tolerated (0.76); PolyPhen benign (0.015); catalogued as COSV57493406; called by muse, mutect2, varscan2
- PDZK1 | c.1186C>T p.R396W | Missense Mutation (SNP) | VAF 52/170 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.846); catalogued as rs1477089107, COSV100572408; called by muse, mutect2, varscan2
- PEPD | c.1292G>A p.R431H | Missense Mutation (SNP) | VAF 17/45 reads (38%) | SIFT tolerated (0.55); PolyPhen benign (0.003); catalogued as rs763642654, COSV54887448; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- PGR | c.2212+2T>C p.X738_splice | Splice Site (SNP) | VAF 26/78 reads (33%) | catalogued as COSV54796985; called by muse, mutect2, varscan2
- PHACTR1 | c.759del p.P254Qfs*59 | Frame Shift Del (DEL) | VAF 12/36 reads (33%) | catalogued as rs749326031; called by mutect2, varscan2
- PHACTR4 | c.1022G>A p.R341H (on ENST00000373839 / NM_001350159.2; = p.R351H on NM_023923.4) | Missense Mutation (SNP) | VAF 17/56 reads (30%) | SIFT tolerated (0.08); PolyPhen benign (0.057); catalogued as rs775752459, COSV65783245; called by muse, varscan2
- PHF2 | c.2858del p.K953Rfs*7 | Frame Shift Del (DEL) | VAF 18/47 reads (38%) | catalogued as rs1252501615; called by mutect2, varscan2
- PHKA2 | c.1421A>G p.Q474R | Missense Mutation (SNP) | VAF 19/25 reads (76%) | SIFT deleterious (0.03); PolyPhen benign (0.444); catalogued as COSV66052694; called by muse, mutect2, varscan2
- PHLDB1 | c.2117G>A p.S706N | Missense Mutation (SNP) | VAF 10/21 reads (48%) | SIFT tolerated (0.24); PolyPhen benign (0.042); catalogued as COSV61876722; called by muse, mutect2, varscan2
- PHLDB2 | c.1719G>T p.K573N | Missense Mutation (SNP) | VAF 5/21 reads (24%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.526); catalogued as COSV67308629; called by muse, mutect2, varscan2
- PIH1D1 | c.594del p.R200Efs*11 | Frame Shift Del (DEL) | VAF 8/12 reads (67%) | catalogued as COSV51808181; called by mutect2, varscan2
- PIK3R2 | c.1256C>T p.T419I | Missense Mutation (SNP) | VAF 24/63 reads (38%) | SIFT tolerated (0.36); PolyPhen benign (0.154); catalogued as COSV55846928; called by muse, mutect2, varscan2
- PIK3R5 | c.239del p.P80Rfs*24 | Frame Shift Del (DEL) | VAF 7/23 reads (30%) | catalogued as COSV52658686, COSV52658933; called by mutect2, pindel
- PKD1 | c.10745del p.P3582Rfs*3 (on ENST00000262304 / NM_001009944.3; = p.P3581Rfs*3 on NM_000296.4) | Frame Shift Del (DEL) | VAF 7/21 reads (33%) | catalogued as CD076868; called by mutect2, pindel, varscan2
- PKLR | c.787G>A p.G263R | Missense Mutation (SNP) | VAF 23/58 reads (40%) | SIFT deleterious (0); PolyPhen benign (0.44); catalogued as rs1253386414, CM971206, CM971207, COSV100713008, COSV61360559; called by muse, mutect2, varscan2
- PKMYT1 | c.316_318del p.F106del | In Frame Del (DEL) | VAF 16/54 reads (30%) | catalogued as rs750629453; called by pindel, varscan2
- PLAU | c.446A>G p.H149R | Missense Mutation (SNP) | VAF 16/50 reads (32%) | SIFT tolerated (0.23); PolyPhen benign (0.003); catalogued as rs1380288173, COSV65640883; called by muse, mutect2, varscan2
- PLCG1 | c.2792A>T p.Q931L | Missense Mutation (SNP) | VAF 15/39 reads (38%) | SIFT tolerated (0.21); PolyPhen benign (0.005); catalogued as COSV54815736; called by muse, mutect2, varscan2
- PLCG2 | c.3002G>A p.R1001H | Missense Mutation (SNP) | VAF 4/23 reads (17%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.998); catalogued as rs752209691, COSV63867371; called by muse, mutect2, varscan2
- PLCH1 | c.3575C>T p.P1192L (on ENST00000340059 / NM_001130960.2; = p.P1184L on NM_014996.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 16/48 reads (33%) | SIFT tolerated, low confidence (0.42); PolyPhen benign (0); catalogued as rs768535202, COSV58188799; called by muse, mutect2, varscan2
- PLCL2 | c.1213T>C p.F405L (on ENST00000615277 / NM_001144382.2; = p.F279L on NM_015184.5) | Missense Mutation (SNP) | VAF 69/182 reads (38%) | SIFT tolerated (0.07); PolyPhen benign (0.232); catalogued as COSV67620759; called by muse, mutect2, varscan2
- PLEKHA1 | c.487T>C p.C163R | Missense Mutation (SNP) | VAF 11/39 reads (28%) | SIFT tolerated (0.53); PolyPhen benign (0.039); catalogued as rs1247171065, COSV64569017; called by muse, mutect2, varscan2
- PLEKHA1 | c.934G>A p.A312T | Missense Mutation (SNP) | VAF 13/47 reads (28%) | SIFT tolerated (0.39); PolyPhen benign (0); catalogued as rs765456729, COSV64569024; called by muse, mutect2, varscan2
- PLEKHA6 | c.2119T>C p.F707L | Missense Mutation (SNP) | VAF 20/58 reads (34%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.914); catalogued as rs1219451630, COSV55330606; called by muse, varscan2
- PLEKHG4B | c.1108C>A p.L370M (on ENST00000283426; = p.L726M on NM_052909.5) | Missense Mutation (SNP) | VAF 13/38 reads (34%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.992); catalogued as rs770549223, COSV52044250; called by muse, mutect2, varscan2
- PLEKHG7 | c.254C>A p.S85* | Nonsense Mutation (SNP) | VAF 8/22 reads (36%) | catalogued as COSV67337721, COSV67337885; called by muse, mutect2, varscan2
- PLEKHO1 | c.1000C>T p.R334* | Nonsense Mutation (SNP) | VAF 27/81 reads (33%) | catalogued as COSV50309842; called by muse, mutect2, varscan2
- PLIN5 | c.677G>A p.R226H | Missense Mutation (SNP) | VAF 4/24 reads (17%) | SIFT tolerated (0.34); PolyPhen benign (0.003); catalogued as rs762891297; called by mutect2, varscan2
- PLS1 | c.146G>A p.G49D | Missense Mutation (SNP) | VAF 12/42 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1258064930, COSV61832889; called by muse, mutect2, varscan2
- PLXNA3 | c.48_49dup p.A17Gfs*13 | Frame Shift Ins (INS) | VAF 10/26 reads (38%) | catalogued as rs782247826; called by mutect2, varscan2
- PLXNA4 | c.5044C>A p.L1682M | Missense Mutation (SNP) | VAF 20/67 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV58108025; called by muse, mutect2, varscan2
- PLXNA4 | c.2140G>A p.V714M | Missense Mutation (SNP) | VAF 8/30 reads (27%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.953); catalogued as rs1308095027, COSV58108045; called by muse, mutect2, varscan2
- PLXNA4 | c.1894G>A p.V632I | Missense Mutation (SNP) | VAF 19/46 reads (41%) | SIFT tolerated (0.51); PolyPhen benign (0.001); catalogued as rs768011905, COSV58108072; called by muse, mutect2, varscan2
- PLXNB3 | c.4963del p.V1655Cfs*7 | Frame Shift Del (DEL) | VAF 10/16 reads (63%) | catalogued as rs782076287; called by mutect2, varscan2
- POSTN | c.1422G>T p.E474D | Missense Mutation (SNP) | VAF 39/92 reads (42%) | SIFT tolerated (0.11); PolyPhen benign (0.154); catalogued as COSV65712037; called by muse, mutect2, varscan2
- POU3F4 | c.254G>A p.R85H | Missense Mutation (SNP) | VAF 29/41 reads (71%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.967); catalogued as rs1248678436, COSV64537957; called by muse, mutect2, varscan2
- PPAT | c.611G>A p.R204H | Missense Mutation (SNP) | VAF 27/67 reads (40%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.918); catalogued as COSV51703162; called by muse, mutect2, varscan2
- PPIP5K1 | c.3832C>T p.P1278S (on ENST00000396923; = p.P1253S on NM_014659.5 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 35/85 reads (41%) | SIFT tolerated, low confidence (0.18); PolyPhen benign (0.001); catalogued as COSV55806568; called by muse, mutect2, varscan2
- PPP1R16A | c.1262G>A p.R421Q | Missense Mutation (SNP) | VAF 15/59 reads (25%) | SIFT tolerated (0.29); PolyPhen benign (0.022); catalogued as rs559264971, COSV52952351; called by muse, mutect2, varscan2
- PPP1R2 | c.287C>T p.A96V | Missense Mutation (SNP) | VAF 38/93 reads (41%) | SIFT tolerated (0.08); PolyPhen benign (0.003); catalogued as COSV60497200; called by muse, mutect2, varscan2
- PPP3CA | c.1172C>T p.A391V | Missense Mutation (SNP) | VAF 28/105 reads (27%) | SIFT tolerated (0.27); PolyPhen benign (0.005); catalogued as COSV59920137; called by muse, mutect2, varscan2
- PPP4R1 | c.164C>T p.A55V (on ENST00000400556 / NM_001042388.3; = p.A38V on NM_005134.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 20/43 reads (47%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.766); catalogued as COSV53280638; called by muse, mutect2, varscan2
- PREX2 | c.895C>T p.R299W | Missense Mutation (SNP) | VAF 46/142 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs771902674, COSV55753696; called by muse, mutect2, varscan2
- PRPF3 | c.933del p.F311Lfs*69 | Frame Shift Del (DEL) | VAF 12/71 reads (17%) | catalogued as rs34541287; called by mutect2, pindel, varscan2
- PSD2 | c.1288T>C p.S430P | Missense Mutation (SNP) | VAF 6/32 reads (19%) | SIFT deleterious (0); PolyPhen benign (0.155); catalogued as COSV99217140; called by muse, mutect2, varscan2
- PSMG3 | c.104T>C p.V35A | Missense Mutation (SNP) | VAF 9/32 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV52920436; called by muse, mutect2, varscan2
- PSTK | c.671T>G p.L224R | Missense Mutation (SNP) | VAF 10/28 reads (36%) | SIFT deleterious (0); PolyPhen possibly damaging (0.843); catalogued as COSV64398231; called by muse, mutect2
- PTCH1 | c.290dup p.N97Kfs*43 | Frame Shift Ins (INS) | VAF 7/37 reads (19%) | catalogued as COSV59501459; called by mutect2, varscan2
- PTHLH | c.503C>T p.T168M | Missense Mutation (SNP) | VAF 40/113 reads (35%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.011); catalogued as rs1463175258, COSV52366518; called by muse, mutect2, varscan2
- PTPDC1 | c.1636C>T p.R546* (on ENST00000375360 / NM_177995.3; = p.R598* on NM_152422.4) | Nonsense Mutation (SNP) | VAF 18/45 reads (40%) | catalogued as rs923336102, COSV56621814; called by muse, mutect2, varscan2
- PTPRF | c.810G>T p.E270D | Missense Mutation (SNP) | VAF 7/38 reads (18%) | SIFT tolerated (0.14); PolyPhen benign (0.067); catalogued as COSV63443017; called by muse, mutect2, varscan2
- PTPRK | c.3092G>T p.R1031M (on ENST00000368215 / NM_001291984.2; = p.R1032M on NM_002844.4) | Missense Mutation (SNP) | VAF 46/124 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as COSV63891972; called by muse, mutect2, varscan2
- PTPRS | c.5161C>T p.R1721W | Missense Mutation (SNP) | VAF 24/69 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1351895585, COSV53611790; called by muse, mutect2, varscan2
- PUM1 | c.3500A>G p.Y1167C | Missense Mutation (SNP) | VAF 7/29 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); catalogued as COSV99927843; called by muse, mutect2, varscan2
- PUM2 | c.2453A>G p.K818R | Missense Mutation (SNP) | VAF 30/98 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.733); catalogued as COSV57578265; called by muse, mutect2, varscan2
- PUS3 | c.586C>T p.R196C | Missense Mutation (SNP) | VAF 14/31 reads (45%) | SIFT deleterious (0); PolyPhen benign (0.058); catalogued as rs370110541, COSV99917076; called by muse, mutect2, varscan2
- PUS7L | c.919C>A p.L307I | Missense Mutation (SNP) | VAF 5/62 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100786516; called by muse, mutect2
- PXDN | c.2488G>A p.D830N | Missense Mutation (SNP) | VAF 9/34 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as COSV53227915; called by muse, mutect2, varscan2
- PXDNL | c.2185G>A p.A729T | Missense Mutation (SNP) | VAF 26/44 reads (59%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as rs1336997230, COSV62478398; called by muse, mutect2, varscan2
- QSER1 | c.3202C>T p.H1068Y (on ENST00000399302; = p.H1197Y on NM_001076786.3) | Missense Mutation (SNP) | VAF 18/60 reads (30%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV67899666; called by muse, mutect2, varscan2
- QSOX2 | c.471T>G p.N157K | Missense Mutation (SNP) | VAF 11/38 reads (29%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.903); catalogued as COSV62393476, COSV62395624; called by muse, mutect2, varscan2
- QTRT2 | c.1126G>A p.G376R | Missense Mutation (SNP) | VAF 42/126 reads (33%) | SIFT tolerated (0.23); PolyPhen benign (0.005); catalogued as rs535717568, COSV55558966; called by muse, mutect2, varscan2
- RAB3IL1 | c.77C>T p.T26M | Missense Mutation (SNP) | VAF 14/32 reads (44%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.015); catalogued as rs374291951; called by muse, mutect2, varscan2
- RABGEF1 | c.1316G>T p.R439M (on ENST00000439720 / NM_001287061.2; = p.R426M on NM_014504.3 and 29 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 18/72 reads (25%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.619); catalogued as COSV99534732; called by muse, mutect2, varscan2
- RAD50 | c.197T>C p.F66S | Missense Mutation (SNP) | VAF 50/138 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV54748282; called by muse, mutect2, varscan2
- RAD51AP1 | c.208del p.R70Dfs*21 (on ENST00000228843 / NM_001130862.2; = p.R70Gfs*4 on NM_006479.5) | Frame Shift Del (DEL) | VAF 46/139 reads (33%) | catalogued as rs745353960; called by mutect2, pindel, varscan2
- RALGAPA2 | c.3637T>C p.S1213P | Missense Mutation (SNP) | VAF 16/43 reads (37%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.65); catalogued as COSV52489709; called by muse, mutect2, varscan2
- RASGRP2 | c.607G>A p.V203I | Missense Mutation (SNP) | VAF 13/37 reads (35%) | SIFT tolerated (0.45); PolyPhen benign (0.131); catalogued as rs776573272, COSV62448871; called by muse, mutect2, varscan2
- RASL12 | c.28G>A p.A10T | Missense Mutation (SNP) | VAF 5/12 reads (42%) | SIFT tolerated, low confidence (0.27); PolyPhen benign (0.007); catalogued as COSV54981145; called by muse, varscan2
- RASSF4 | c.441C>G p.S147R | Missense Mutation (SNP) | VAF 19/40 reads (48%) | SIFT tolerated (0.58); PolyPhen benign (0.081); catalogued as COSV58484728; called by muse, mutect2, varscan2
- RAVER1 | c.1071del p.K358Sfs*177 (on ENST00000615032; = p.K358Sfs*149 on NM_133452.3 and 1 other RefSeq transcript) | Frame Shift Del (DEL) | VAF 14/44 reads (32%) | catalogued as rs773370779, COSV99532335; called by mutect2, varscan2
- RBM10 | c.1702G>A p.D568N | Missense Mutation (SNP) | VAF 4/34 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.731); catalogued as COSV61308396; called by muse, mutect2
- RBM25 | c.1261C>T p.R421W | Missense Mutation (SNP) | VAF 23/60 reads (38%) | SIFT deleterious (0); PolyPhen benign (0.42); catalogued as rs750883608, COSV56198761; called by muse, mutect2, varscan2
- RECQL | c.1213G>A p.A405T | Missense Mutation (SNP) | VAF 13/43 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV69658279; called by muse, mutect2, varscan2
- REEP2 | c.524G>A p.S175N | Missense Mutation (SNP) | VAF 10/33 reads (30%) | SIFT tolerated (0.33); PolyPhen benign (0.017); catalogued as rs1285051301, COSV54734553; called by muse, mutect2, varscan2
- RFPL2 | c.662C>T p.A221V | Missense Mutation (SNP) | VAF 37/102 reads (36%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.458); catalogued as COSV50709015; called by muse, mutect2, varscan2
- RGS11 | c.1328C>G p.P443R (on ENST00000397770 / NM_183337.3; = p.P422R on NM_003834.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 27/56 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); catalogued as COSV51451604; called by muse, mutect2, varscan2
- RGS12 | c.3870del p.Q1292Rfs*49 | Frame Shift Del (DEL) | VAF 12/26 reads (46%) | catalogued as rs751982308; called by mutect2, varscan2
- RHOBTB3 | c.1567A>G p.S523G | Missense Mutation (SNP) | VAF 17/54 reads (31%) | SIFT deleterious (0.01); PolyPhen benign (0.066); catalogued as COSV66101249; called by muse, mutect2, varscan2
- RHOQ | c.499A>G p.T167A | Missense Mutation (SNP) | VAF 88/266 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.894); catalogued as COSV53189494; called by muse, mutect2, varscan2
- RIMBP2 | c.1930G>A p.G644S | Missense Mutation (SNP) | VAF 16/35 reads (46%) | SIFT tolerated (0.55); PolyPhen benign (0.115); catalogued as COSV55466232; called by muse, mutect2, varscan2
- RIMS1 | c.2399C>T p.T800I | Missense Mutation (SNP) | VAF 22/59 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV53441758; called by muse, mutect2, varscan2
- RNF165 | c.277G>A p.V93I | Missense Mutation (SNP) | VAF 5/25 reads (20%) | SIFT tolerated (0.27); PolyPhen benign (0.001); catalogued as COSV53971428; called by muse, mutect2, varscan2
- RNF169 | c.902C>T p.A301V | Missense Mutation (SNP) | VAF 17/38 reads (45%) | SIFT tolerated (0.53); PolyPhen benign (0.001); catalogued as rs375919416; called by muse, mutect2, varscan2
- RNF213 | c.5794G>T p.G1932W | Missense Mutation (SNP) | VAF 16/41 reads (39%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.753); catalogued as COSV60391495; called by muse, mutect2, varscan2
- RNF214 | c.1675C>A p.L559M | Missense Mutation (SNP) | VAF 14/32 reads (44%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.896); catalogued as COSV56117808; called by muse, mutect2, varscan2
- RNF43 | c.1976del p.G659Vfs*41 | Frame Shift Del (DEL) | VAF 43/58 reads (74%) | catalogued as rs755128667, COSV68457540; called by mutect2, varscan2
- RNF43 | c.199G>T p.G67C | Missense Mutation (SNP) | VAF 24/51 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV60415475; called by muse, mutect2, varscan2
- RNMT | c.1067G>A p.C356Y | Missense Mutation (SNP) | VAF 49/116 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV51084210; called by muse, mutect2, varscan2
- ROBO2 | c.3233dup p.V1079Sfs*22 | Frame Shift Ins (INS) | VAF 29/89 reads (33%) | catalogued as rs745519558; called by mutect2, varscan2
- ROBO4 | c.1679G>A p.R560H | Missense Mutation (SNP) | VAF 10/21 reads (48%) | SIFT tolerated (0.26); PolyPhen possibly damaging (0.869); catalogued as rs986434452; called by muse, mutect2, varscan2
- ROR2 | c.1207G>T p.G403W | Missense Mutation (SNP) | VAF 10/40 reads (25%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.715); catalogued as COSV65216859; called by muse, mutect2, varscan2
- RP1L1 | c.1261G>A p.A421T | Missense Mutation (SNP) | VAF 10/41 reads (24%) | SIFT tolerated (0.14); PolyPhen benign (0.175); catalogued as COSV66752312; called by muse, mutect2, varscan2
- RPF1 | c.238G>A p.A80T | Missense Mutation (SNP) | VAF 51/144 reads (35%) | SIFT tolerated (0.22); PolyPhen benign (0.079); catalogued as rs1246902341, COSV65723967; called by muse, mutect2, varscan2
- RPH3A | c.244C>T p.R82C (on ENST00000389385 / NM_001143854.2; = p.R78C on NM_014954.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 25/45 reads (56%) | SIFT deleterious (0); PolyPhen probably damaging (0.945); catalogued as rs769217929, COSV66990129, COSV66990818; called by muse, mutect2, varscan2
- RPH3A | c.643A>T p.K215* (on ENST00000389385 / NM_001143854.2; = p.K211* on NM_014954.4 and 1 other RefSeq transcript) | Nonsense Mutation (SNP) | VAF 31/84 reads (37%) | catalogued as COSV66990132; called by muse, mutect2, varscan2
- RRM2B | c.226C>A p.P76T | Missense Mutation (SNP) | VAF 9/36 reads (25%) | SIFT tolerated, low confidence (0.63); PolyPhen benign (0.006); catalogued as COSV52565813; called by muse, mutect2, varscan2
- RTTN | c.3578G>A p.R1193Q | Missense Mutation (SNP) | VAF 20/52 reads (38%) | SIFT tolerated (0.75); PolyPhen benign (0); catalogued as COSV55341924; called by muse, mutect2, varscan2
- RXFP3 | c.416C>T p.A139V | Missense Mutation (SNP) | VAF 4/48 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57504071; called by muse, mutect2
- RYK | c.331T>G p.F111V | Missense Mutation (SNP) | VAF 13/39 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.925); catalogued as COSV99938375; called by muse, mutect2, varscan2
- RYR3 | c.3479T>C p.I1160T | Missense Mutation (SNP) | VAF 33/109 reads (30%) | SIFT tolerated (0.27); PolyPhen benign (0.111); catalogued as COSV66779710; called by muse, mutect2, varscan2
- SACS | c.11050G>A p.G3684R | Missense Mutation (SNP) | VAF 17/52 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs371734450; called by muse, mutect2, varscan2
- SAXO2 | c.52G>T p.G18W | Missense Mutation (SNP) | VAF 26/80 reads (33%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.772); catalogued as COSV51603117; called by muse, mutect2, varscan2
- SBF2 | c.4517C>A p.S1506Y | Missense Mutation (SNP) | VAF 8/23 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV56292621; called by muse, mutect2, varscan2
- SBNO1 | c.4006C>T p.R1336W (on ENST00000420886; = p.R1335W on NM_018183.5) | Missense Mutation (SNP) | VAF 41/111 reads (37%) | SIFT deleterious (0); PolyPhen possibly damaging (0.548); catalogued as COSV57339340; called by muse, mutect2, varscan2
- SCAF11 | c.1804del p.T602Qfs*5 | Frame Shift Del (DEL) | VAF 24/84 reads (29%) | catalogued as rs1369561311; called by mutect2, pindel, varscan2
- SCN5A | c.3925C>A p.R1309S (on ENST00000333535 / NM_198056.3; = p.R1308S on NM_000335.5) | Missense Mutation (SNP) | VAF 17/45 reads (38%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV100351372, COSV61117528; called by muse, mutect2, varscan2
- SCNN1A | c.1988C>T p.T663I | Missense Mutation (SNP) | VAF 7/37 reads (19%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0); catalogued as rs762689971, COSV57434263; called by muse, mutect2, varscan2
- SCUBE2 | c.953G>A p.G318E | Missense Mutation (SNP) | VAF 5/16 reads (31%) | SIFT deleterious (0.05); PolyPhen probably damaging (1); catalogued as rs745931406; called by muse, mutect2, varscan2
- SDAD1 | c.824del p.K275Rfs*15 | Frame Shift Del (DEL) | VAF 11/36 reads (31%) | catalogued as rs763181092; called by mutect2, varscan2
- SDC1 | c.627G>T p.Q209H | Missense Mutation (SNP) | VAF 18/43 reads (42%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.756); catalogued as COSV54339129; called by muse, mutect2, varscan2
- SDK2 | c.1474G>A p.V492I | Missense Mutation (SNP) | VAF 16/45 reads (36%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.483); catalogued as rs376227214; called by muse, mutect2, varscan2
- SEC14L4 | c.1022G>A p.R341H | Missense Mutation (SNP) | VAF 19/49 reads (39%) | SIFT tolerated (0.09); PolyPhen benign (0.188); catalogued as rs368386943; called by muse, mutect2, varscan2
- SEC16B | c.1299del p.S434Vfs*29 | Frame Shift Del (DEL) | VAF 8/28 reads (29%) | catalogued as rs768388757; called by mutect2, varscan2
- SEC24B | c.1925A>G p.N642S | Missense Mutation (SNP) | VAF 18/47 reads (38%) | SIFT deleterious (0); PolyPhen possibly damaging (0.827); catalogued as rs1561161064, COSV54496049; called by muse, mutect2, varscan2
- SEMA3E | c.1717T>C p.F573L | Missense Mutation (SNP) | VAF 9/18 reads (50%) | SIFT tolerated (0.65); PolyPhen benign (0); catalogued as COSV57081115; called by muse, mutect2, varscan2
- SEMA3E | c.1563G>A p.M521I | Missense Mutation (SNP) | VAF 30/79 reads (38%) | SIFT tolerated (0.62); PolyPhen benign (0.017); catalogued as rs138211552; called by muse, mutect2, varscan2
- SEMA5B | c.2677G>A p.V893M | Missense Mutation (SNP) | VAF 22/56 reads (39%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.686); catalogued as rs779789464, COSV52091775; called by muse, mutect2, varscan2
- SEMA6C | c.1846C>A p.L616M | Missense Mutation (SNP) | VAF 6/15 reads (40%) | SIFT tolerated (0.28); PolyPhen benign (0.034); catalogued as COSV59000467; called by muse, mutect2, varscan2
- SERPINF2 | c.4G>A p.A2T | Missense Mutation (SNP) | VAF 9/17 reads (53%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.009); catalogued as COSV60663641; called by muse, mutect2, varscan2
- SETBP1 | c.630C>A p.H210Q | Missense Mutation (SNP) | VAF 10/25 reads (40%) | SIFT deleterious (0); PolyPhen benign (0.135); catalogued as COSV56314261; called by muse, mutect2, varscan2
- SETD5 | c.3610A>G p.N1204D | Missense Mutation (SNP) | VAF 5/24 reads (21%) | SIFT tolerated (0.17); PolyPhen benign (0.001); catalogued as rs776405933, COSV56708027; called by mutect2, varscan2
- SF3B1 | c.2003T>C p.V668A | Missense Mutation (SNP) | VAF 22/74 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.624); catalogued as COSV59208178; called by muse, varscan2
- SF3B1 | c.25G>A p.E9K | Missense Mutation (SNP) | VAF 6/23 reads (26%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.001); catalogued as COSV59208189; called by muse, mutect2, varscan2
- SGCD | c.9G>T p.Q3H (on ENST00000435422 / NM_001128209.2; = p.Q4H on NM_000337.5) | Missense Mutation (SNP) | VAF 43/137 reads (31%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.965); catalogued as COSV61904630; called by muse, mutect2, varscan2
- SGK1 | c.1163A>G p.E388G | Missense Mutation (SNP) | VAF 24/61 reads (39%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.908); catalogued as COSV52805400; called by muse, varscan2
- SHE | c.1012C>T p.R338W | Missense Mutation (SNP) | VAF 21/49 reads (43%) | SIFT deleterious (0); PolyPhen possibly damaging (0.849); catalogued as rs553525893, COSV59070928; called by muse, mutect2, varscan2
- SHPRH | c.1371del p.G458Efs*26 | Frame Shift Del (DEL) | VAF 32/84 reads (38%) | catalogued as rs774210627; called by mutect2, varscan2
- SKA3 | c.747G>T p.E249D | Missense Mutation (SNP) | VAF 26/80 reads (33%) | SIFT tolerated (0.31); PolyPhen possibly damaging (0.613); catalogued as COSV53433900; called by muse, mutect2, varscan2
- SLC12A2 | c.3478T>C p.S1160P | Missense Mutation (SNP) | VAF 80/212 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV52468801; called by muse, mutect2, varscan2
- SLC15A1 | c.2074G>A p.E692K | Missense Mutation (SNP) | VAF 39/101 reads (39%) | SIFT tolerated (0.29); PolyPhen benign (0.003); catalogued as COSV64730208; called by muse, mutect2, varscan2
- SLC1A5 | c.989G>A p.R330H | Missense Mutation (SNP) | VAF 16/61 reads (26%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.989); catalogued as rs749537352, COSV69466512; called by muse, mutect2, varscan2
- SLC24A2 | c.1880G>A p.R627Q | Missense Mutation (SNP) | VAF 30/84 reads (36%) | SIFT deleterious (0); PolyPhen possibly damaging (0.523); catalogued as rs749916427, COSV53858529; called by muse, mutect2, varscan2
- SLC27A1 | c.1459G>A p.A487T | Missense Mutation (SNP) | VAF 7/21 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.966); catalogued as rs1568424613, COSV53095531; called by muse, mutect2, varscan2
- SLC30A3 | c.613del p.H205Tfs*260 | Frame Shift Del (DEL) | VAF 19/45 reads (42%) | catalogued as rs745429257; called by mutect2, pindel, varscan2
- SLC36A1 | c.1057G>A p.V353I | Missense Mutation (SNP) | VAF 36/119 reads (30%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.452); catalogued as rs781266508, COSV54652308, COSV54655236; called by muse, mutect2, varscan2
- SLC38A1 | c.736A>G p.I246V | Missense Mutation (SNP) | VAF 42/124 reads (34%) | SIFT tolerated (0.14); PolyPhen benign (0); catalogued as COSV67062975; called by muse, varscan2
- SLC38A10 | c.2702C>T p.A901V | Missense Mutation (SNP) | VAF 20/60 reads (33%) | SIFT tolerated (0.09); PolyPhen benign (0.052); catalogued as rs1222146332, COSV55843131; called by muse, mutect2, varscan2
- SLC39A4 | c.1546G>T p.G516C (on ENST00000301305 / NM_001374839.1; = p.G491C on NM_017767.3) | Missense Mutation (SNP) | VAF 10/37 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52777793; called by muse, mutect2
- SLC3A2 | c.899del p.K300Rfs*31 | Frame Shift Del (DEL) | VAF 32/80 reads (40%) | catalogued as rs760089491; called by mutect2, varscan2
- SLC4A10 | c.158A>G p.H53R | Missense Mutation (SNP) | VAF 16/65 reads (25%) | SIFT tolerated (0.31); PolyPhen benign (0.015); catalogued as COSV55766348; called by muse, mutect2, varscan2
- SLC6A5 | c.2241G>A p.R747= | Splice Region (SNP) | VAF 22/55 reads (40%) | catalogued as COSV54224156; called by muse, mutect2, varscan2
- SLC8A2 | c.496G>A p.V166M | Missense Mutation (SNP) | VAF 17/43 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52638092; called by muse, mutect2, varscan2
- SLCO5A1 | c.1441A>G p.S481G | Missense Mutation (SNP) | VAF 26/78 reads (33%) | SIFT tolerated (0.84); PolyPhen possibly damaging (0.46); catalogued as COSV52654479; called by muse, mutect2
- SLIT2 | c.3379A>T p.N1127Y | Missense Mutation (SNP) | VAF 16/45 reads (36%) | SIFT tolerated (0.5); PolyPhen benign (0.026); catalogued as COSV56562095; called by muse, mutect2, varscan2
- SLITRK6 | c.1487A>G p.H496R | Missense Mutation (SNP) | VAF 26/73 reads (36%) | SIFT tolerated (0.06); PolyPhen benign (0.091); catalogued as COSV68389498; called by muse, mutect2, varscan2
- SMC1B | c.572dup p.N191Kfs*24 | Frame Shift Ins (INS) | VAF 37/108 reads (34%) | catalogued as rs748761052; called by mutect2, varscan2
- SMG6 | c.2557C>A p.L853M | Missense Mutation (SNP) | VAF 32/83 reads (39%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.972); catalogued as COSV53963658; called by muse, mutect2, varscan2
- SMIM29 | c.92G>A p.R31H (on ENST00000394990 / NM_001008704.3; = p.R51H on NM_178508.5) | Missense Mutation (SNP) | VAF 9/25 reads (36%) | SIFT deleterious (0.02); PolyPhen benign (0.015); catalogued as rs761702562, COSV58988220, COSV58988903; called by muse, mutect2, varscan2
- SMOX | c.908dup p.R304Qfs*4 | Frame Shift Ins (INS) | VAF 59/152 reads (39%) | catalogued as rs746816975; called by mutect2, varscan2
- SNAPC2 | c.799del p.Q267Sfs*38 | Frame Shift Del (DEL) | VAF 4/32 reads (13%) | catalogued as rs769564442; called by pindel, varscan2
- SNRPN | c.261del p.D89Ifs*53 | Frame Shift Del (DEL) | VAF 21/59 reads (36%) | catalogued as rs1566976799; called by mutect2, pindel, varscan2
- SNTB1 | c.1439A>C p.Q480P | Missense Mutation (SNP) | VAF 24/110 reads (22%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.514); catalogued as rs749144227, COSV67324764; called by muse, mutect2, varscan2
- SOCS6 | c.298G>A p.D100N | Missense Mutation (SNP) | VAF 26/61 reads (43%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.036); catalogued as COSV67546016; called by muse, mutect2, varscan2
- SOX5 | c.2181G>T p.Q727H | Missense Mutation (SNP) | VAF 37/105 reads (35%) | SIFT tolerated (0.25); PolyPhen benign (0); catalogued as COSV58620282; called by muse, mutect2, varscan2
- SPAG1 | c.1517G>A p.C506Y | Missense Mutation (SNP) | VAF 35/114 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52558270; called by muse, mutect2, varscan2
- SPATA31E1 | c.875T>C p.V292A | Missense Mutation (SNP) | VAF 7/28 reads (25%) | SIFT tolerated (1); PolyPhen benign (0.005); catalogued as COSV100350266; called by muse, mutect2, varscan2
- SPDYE1 | c.641C>T p.A214V | Missense Mutation (SNP) | VAF 54/132 reads (41%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.981); catalogued as COSV51669693; called by muse, mutect2, varscan2
- SSPOP | n.5914C>T | Splice Region (SNP) | VAF 7/33 reads (21%) | catalogued as rs766325783, COSV50486598; called by muse, mutect2, varscan2
- STAB1 | c.5842C>T p.R1948C | Missense Mutation (SNP) | VAF 6/25 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as rs768136055, COSV100195216, COSV58732796; called by muse, mutect2, varscan2
- STAMBPL1 | c.1214del p.K405Rfs*21 | Frame Shift Del (DEL) | VAF 20/39 reads (51%) | catalogued as rs752994755; called by mutect2, varscan2
- STAU1 | c.241T>C p.C81R | Missense Mutation (SNP) | VAF 32/90 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); catalogued as COSV61459139; called by muse, mutect2, varscan2
- STMN2 | c.188C>A p.P63H | Missense Mutation (SNP) | VAF 17/54 reads (31%) | SIFT tolerated (0.18); PolyPhen probably damaging (0.999); catalogued as COSV55218167; called by muse, mutect2, varscan2
- STRC | c.4282A>T p.R1428* | Nonsense Mutation (SNP) | VAF 26/76 reads (34%) | catalogued as COSV55851928; called by muse, mutect2, varscan2
- STX18 | c.35G>A p.S12N | Missense Mutation (SNP) | VAF 9/27 reads (33%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.983); catalogued as COSV60371878; called by muse, mutect2, varscan2
- STYK1 | c.713C>T p.A238V | Missense Mutation (SNP) | VAF 22/69 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs753170900, COSV50012474; called by muse, mutect2, varscan2
- SUCLG2 | c.1007G>A p.G336D | Missense Mutation (SNP) | VAF 15/47 reads (32%) | SIFT deleterious (0); PolyPhen possibly damaging (0.845); catalogued as COSV56202611; called by muse, mutect2, varscan2
- SUN1 | c.1803C>A p.H601Q (on ENST00000405266 / NM_001367651.1; = p.H481Q on NM_025154.6 and 13 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 10/23 reads (43%) | SIFT tolerated (0.34); PolyPhen benign (0.007); catalogued as COSV67447981; called by muse, mutect2, varscan2
- SUPT16H | c.1517G>A p.R506H | Missense Mutation (SNP) | VAF 25/76 reads (33%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.927); catalogued as rs1185247895, COSV53522556; called by muse, mutect2, varscan2
- SV2C | c.815G>A p.R272Q | Missense Mutation (SNP) | VAF 9/45 reads (20%) | SIFT tolerated (0.35); PolyPhen benign (0.094); catalogued as rs13153247, COSV59215070; called by muse, mutect2, varscan2
- SYDE2 | c.1532C>A p.S511* | Nonsense Mutation (SNP) | VAF 19/58 reads (33%) | catalogued as COSV52314298; called by muse, mutect2, varscan2
- SYNE1 | c.15587G>A p.R5196Q (on ENST00000367255 / NM_182961.4; = p.R5125Q on NM_033071.3) | Missense Mutation (SNP) | VAF 31/110 reads (28%) | SIFT deleterious (0.03); PolyPhen benign (0.261); catalogued as rs752229373, COSV99560241; called by muse, mutect2, varscan2
- SYNE2 | c.18565C>T p.R6189W | Missense Mutation (SNP) | VAF 8/19 reads (42%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.893); catalogued as rs1366404251, COSV59941251; called by muse, mutect2, varscan2
- TAF11 | c.124G>T p.G42* | Nonsense Mutation (SNP) | VAF 18/47 reads (38%) | catalogued as rs1392544820; called by muse, mutect2, varscan2
- TAF5L | c.1015C>T p.R339W | Missense Mutation (SNP) | VAF 9/25 reads (36%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.91); catalogued as rs142066323; called by muse, varscan2
- TAF5L | c.998C>T p.T333M | Missense Mutation (SNP) | VAF 8/24 reads (33%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.807); catalogued as rs766868414, COSV51077582; called by muse, varscan2
- TANGO6 | c.2692G>A p.A898T | Missense Mutation (SNP) | VAF 38/115 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV55761373; called by muse, mutect2, varscan2
- TAOK3 | c.1969C>T p.R657* | Nonsense Mutation (SNP) | VAF 44/109 reads (40%) | catalogued as COSV66826720; called by muse, mutect2, varscan2
- TARBP2 | c.521G>A p.R174Q (on ENST00000266987 / NM_134323.2; = p.R153Q on NM_004178.4) | Missense Mutation (SNP) | VAF 17/45 reads (38%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.991); catalogued as COSV57199084; called by muse, mutect2, varscan2
- TBC1D10B | c.2344C>T p.R782C | Missense Mutation (SNP) | VAF 24/88 reads (27%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.68); catalogued as rs1169490479, COSV59768273; called by muse, mutect2, varscan2
- TBC1D12 | c.739G>A p.A247T | Missense Mutation (SNP) | VAF 16/59 reads (27%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0); catalogued as COSV56552635; called by muse, mutect2, varscan2
- TBC1D5 | c.1961G>A p.R654H | Missense Mutation (SNP) | VAF 39/105 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.95); catalogued as rs770540652, COSV53750468; called by muse, mutect2, varscan2
- TCF3 | c.1631C>T p.A544V | Missense Mutation (SNP) | VAF 9/25 reads (36%) | SIFT tolerated (0.25); PolyPhen benign (0.133); catalogued as rs1159035943, COSV53646101; called by muse, mutect2, varscan2
- TCHH | c.3512G>A p.R1171H | Missense Mutation (SNP) | VAF 32/100 reads (32%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.801); catalogued as rs754428406, COSV64273254; called by muse, mutect2, varscan2
- TCHH | c.2653C>T p.R885C | Missense Mutation (SNP) | VAF 81/221 reads (37%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.948); catalogued as COSV64273260; called by muse, mutect2, varscan2
- TDGF1 | c.292C>A p.P98T | Missense Mutation (SNP) | VAF 14/47 reads (30%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.647); catalogued as COSV56125140; called by muse, mutect2, varscan2
- TEAD2 | c.883del p.H295Mfs*12 | Frame Shift Del (DEL) | VAF 16/52 reads (31%) | catalogued as rs763321097; called by mutect2, varscan2
- TET2 | c.2084_2087del p.M695Tfs*4 | Frame Shift Del (DEL) | VAF 33/89 reads (37%) | catalogued as COSV54399095; called by mutect2, pindel, varscan2
- TFAP2D | c.115G>A p.A39T | Missense Mutation (SNP) | VAF 49/116 reads (42%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.959); catalogued as COSV50408971; called by muse, mutect2, varscan2
- TG | c.3554A>G p.Q1185R | Missense Mutation (SNP) | VAF 14/47 reads (30%) | SIFT tolerated (0.1); PolyPhen benign (0.018); catalogued as rs1194947783, COSV55066738; called by muse, mutect2, varscan2
- TGIF2LX | c.14C>T p.A5V | Missense Mutation (SNP) | VAF 48/70 reads (69%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.97); catalogued as rs773985382, COSV52213417; called by muse, mutect2, varscan2
- TGM6 | c.1094-1G>T p.X365_splice | Splice Site (SNP) | VAF 9/25 reads (36%) | catalogued as COSV52477690; called by muse, mutect2, varscan2
- TICAM1 | c.1925del p.P642Hfs*50 | Frame Shift Del (DEL) | VAF 8/22 reads (36%) | catalogued as COSV50235787; called by mutect2, pindel, varscan2
- TIGD2 | c.90dup p.L31Tfs*9 | Frame Shift Ins (INS) | VAF 29/73 reads (40%) | catalogued as rs767961823; called by mutect2, pindel, varscan2
- TMEM218 | c.73del p.L25Cfs*24 | Frame Shift Del (DEL) | VAF 11/43 reads (26%) | catalogued as COSV54444816; called by mutect2, pindel, varscan2
- TNFRSF10A | c.580A>G p.T194A | Missense Mutation (SNP) | VAF 17/71 reads (24%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.954); catalogued as rs1179886430, COSV55324654; called by muse, mutect2, varscan2
- TNK2 | c.326C>T p.A109V | Missense Mutation (SNP) | VAF 17/63 reads (27%) | SIFT tolerated (0.2); PolyPhen benign (0); catalogued as rs763489801, COSV57366157; called by muse, mutect2, varscan2
- TNNI3K | c.2254C>T p.R752W | Missense Mutation (SNP) | VAF 48/98 reads (49%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.23); catalogued as rs202017687; called by muse, mutect2, varscan2
- TNPO3 | c.2660C>T p.A887V | Missense Mutation (SNP) | VAF 53/165 reads (32%) | SIFT tolerated (0.38); PolyPhen benign (0.218); catalogued as COSV55278324; called by muse, mutect2, varscan2
- TNRC6B | c.2653C>T p.R885W | Missense Mutation (SNP) | VAF 13/38 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as rs61743871, COSV57289914; called by muse, mutect2, varscan2
- TNRC6B | c.4522G>A p.G1508S (on ENST00000454349 / NM_001162501.2; = p.G1398S on NM_015088.3) | Missense Mutation (SNP) | VAF 18/47 reads (38%) | SIFT tolerated (0.41); PolyPhen benign (0.269); catalogued as rs767834445, COSV57289930; called by muse, mutect2, varscan2
- TOGARAM1 | c.2021C>T p.T674I | Missense Mutation (SNP) | VAF 8/32 reads (25%) | SIFT tolerated (0.06); PolyPhen benign (0.031); catalogued as COSV61887476; called by muse, mutect2, varscan2
- TOP2A | c.4303del p.R1435Gfs*13 | Frame Shift Del (DEL) | VAF 51/166 reads (31%) | catalogued as rs758129598; called by mutect2, pindel, varscan2
- TOP3B | c.1534G>A p.A512T | Missense Mutation (SNP) | VAF 13/28 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV64116537; called by muse, mutect2, varscan2
- TOR1B | c.640A>G p.S214G | Missense Mutation (SNP) | VAF 23/74 reads (31%) | SIFT deleterious (0); PolyPhen benign (0.176); catalogued as COSV99400116; called by muse, mutect2, varscan2
- TPD52L2 | c.314+2T>C p.X105_splice | Splice Site (SNP) | VAF 10/42 reads (24%) | catalogued as COSV53861645; called by muse, mutect2, varscan2
- TPD52L3 | c.139C>T p.R47C | Missense Mutation (SNP) | VAF 23/56 reads (41%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.996); catalogued as rs754731204, COSV58827882, COSV58827943; called by muse, mutect2, varscan2
- TPST2 | c.437C>T p.A146V | Missense Mutation (SNP) | VAF 7/27 reads (26%) | SIFT tolerated (0.53); PolyPhen benign (0.02); catalogued as COSV58678496; called by muse, mutect2, varscan2
- TRAF4 | c.1087C>A p.L363I | Missense Mutation (SNP) | VAF 36/77 reads (47%) | SIFT tolerated (0.17); PolyPhen benign (0.142); catalogued as COSV52217805; called by muse, mutect2, varscan2
- TRAF5 | c.695C>T p.T232M | Missense Mutation (SNP) | VAF 27/85 reads (32%) | SIFT tolerated (0.09); PolyPhen benign (0); catalogued as rs113925874; called by muse, mutect2, varscan2
- TRAPPC9 | c.1592C>T p.P531L | Missense Mutation (SNP) | VAF 13/22 reads (59%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as rs768262663, COSV66893460; called by muse, mutect2, varscan2
- TRAPPC9 | c.1226G>A p.R409H | Missense Mutation (SNP) | VAF 7/28 reads (25%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.99); catalogued as rs1182738290, COSV66893466; called by muse, mutect2, varscan2
- TRIL | c.80G>A p.C27Y | Missense Mutation (SNP) | VAF 4/12 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.963); catalogued as COSV59867324; called by muse, varscan2
- TRIM21 | c.560del p.N187Tfs*22 | Frame Shift Del (DEL) | VAF 4/30 reads (13%) | catalogued as rs1286630145, COSV54344388; called by pindel, varscan2
- TRIM49 | c.1060G>T p.A354S | Missense Mutation (SNP) | VAF 49/181 reads (27%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.986); catalogued as COSV61670368; called by muse, mutect2, varscan2
- TRIM6 | c.631_633del p.K211del | In Frame Del (DEL) | VAF 12/44 reads (27%) | catalogued as rs748030578; called by pindel, varscan2
- TRIM71 | c.1148T>G p.L383R | Missense Mutation (SNP) | VAF 15/55 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.74); catalogued as COSV67470244; called by muse, mutect2, varscan2
- TRMT9B | c.680C>T p.A227V | Missense Mutation (SNP) | VAF 32/123 reads (26%) | SIFT tolerated (0.36); PolyPhen benign (0.003); catalogued as rs761173357, COSV71600096; called by muse, mutect2, varscan2
- TRPM8 | c.65G>A p.R22Q | Missense Mutation (SNP) | VAF 8/28 reads (29%) | SIFT tolerated (0.33); PolyPhen benign (0.001); catalogued as rs200473098, COSV61220278, COSV61221621; called by muse, mutect2
- TRRAP | c.10151A>C p.N3384T (on ENST00000359863 / NM_001244580.1; = p.N3355T on NM_003496.3) | Missense Mutation (SNP) | VAF 24/60 reads (40%) | SIFT tolerated (0.12); PolyPhen benign (0.091); catalogued as COSV62840110; called by muse, varscan2
- TSHR | c.10G>A p.A4T | Missense Mutation (SNP) | VAF 5/33 reads (15%) | SIFT tolerated, low confidence (0.63); PolyPhen benign (0); catalogued as rs1460409181, COSV53315225; called by muse, mutect2, varscan2
- TSKU | c.205C>T p.R69W | Missense Mutation (SNP) | VAF 19/52 reads (37%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.729); catalogued as rs1292165096, COSV60750936; called by muse, mutect2, varscan2
- TSPAN1 | c.356C>T p.T119M | Missense Mutation (SNP) | VAF 27/85 reads (32%) | SIFT tolerated (0.09); PolyPhen benign (0.131); catalogued as rs924254322, COSV64339391; called by muse, mutect2, varscan2
- TTC31 | c.1433G>A p.R478Q | Missense Mutation (SNP) | VAF 14/49 reads (29%) | SIFT tolerated, low confidence (0.21); PolyPhen benign (0.015); catalogued as rs770774869, COSV52034344; called by muse, mutect2, varscan2
- TTN | c.92210C>T p.T30737I (on ENST00000591111; = p.T23313I on NM_003319.4) | Missense Mutation (SNP) | VAF 32/88 reads (36%) | PolyPhen benign (0.003); catalogued as COSV59909885; called by muse, mutect2, varscan2
- TTN | c.54718C>T p.P18240S (on ENST00000591111; = p.P10816S on NM_003319.4) | Missense Mutation (SNP) | VAF 19/67 reads (28%) | PolyPhen possibly damaging (0.743); catalogued as COSV59909963; called by muse, mutect2, varscan2
- TTN | c.11425G>T p.E3809* (on ENST00000591111; = p.E3763* on NM_003319.4) | Nonsense Mutation (SNP) | VAF 14/41 reads (34%) | catalogued as COSV59880827, COSV59910034; called by muse, mutect2, varscan2
- TTYH2 | c.568del p.V190Cfs*9 | Frame Shift Del (DEL) | VAF 10/30 reads (33%) | catalogued as COSV53908897; called by mutect2, pindel, varscan2
- TUBAL3 | c.1187C>A p.A396D | Missense Mutation (SNP) | VAF 23/48 reads (48%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.938); catalogued as rs782522979, COSV66813985; called by muse, mutect2, varscan2
- TUT1 | c.1603C>T p.R535C | Missense Mutation (SNP) | VAF 8/32 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as rs758242315, COSV53468968; called by muse, mutect2, varscan2
- TYR | c.1185T>C p.S395= | Splice Region (SNP) | VAF 28/86 reads (33%) | catalogued as rs763863353, COSV54470955; called by muse, mutect2, varscan2
- UBR1 | c.904G>A p.V302I | Missense Mutation (SNP) | VAF 39/107 reads (36%) | SIFT tolerated (0.22); PolyPhen benign (0.114); catalogued as COSV51926705; called by muse, mutect2, varscan2
- UBXN11 | c.1337C>A p.P446H (on ENST00000374221 / NM_183008.2; = p.P413H on NM_145345.2) | Missense Mutation (SNP) | VAF 15/36 reads (42%) | SIFT tolerated (0.2); PolyPhen probably damaging (0.921); catalogued as COSV53327430; called by muse, mutect2, varscan2
- UGT2B10 | c.1337G>A p.R446K | Missense Mutation (SNP) | VAF 57/137 reads (42%) | SIFT tolerated (0.19); PolyPhen benign (0.013); catalogued as COSV55318998; called by muse, mutect2, varscan2
- UHRF1 | c.1790G>A p.R597Q (on ENST00000612630 / NM_001290050.1; = p.R610Q on NM_013282.4) | Missense Mutation (SNP) | VAF 12/27 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.943); catalogued as rs1013888086, COSV99503447; called by muse, mutect2, varscan2
- UNC13A | c.2524C>T p.P842S | Missense Mutation (SNP) | VAF 19/38 reads (50%) | SIFT deleterious (0); PolyPhen benign (0.097); catalogued as rs1441456635, COSV53189406; called by muse, mutect2, varscan2
- UNC79 | c.3754+1G>A p.X1252_splice (on ENST00000393151 / NM_001346218.2; = p.X1075_splice on NM_020818.5) | Splice Site (SNP) | VAF 10/41 reads (24%) | catalogued as COSV56376199; called by muse, mutect2, varscan2
- VAMP8 | c.286A>G p.T96A | Missense Mutation (SNP) | VAF 31/105 reads (30%) | SIFT deleterious (0.02); PolyPhen benign (0.18); catalogued as COSV55705055; called by muse, mutect2, varscan2
- VAX2 | c.410G>A p.R137H | Missense Mutation (SNP) | VAF 11/34 reads (32%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.455); catalogued as rs145930788; called by muse, mutect2, varscan2
- VCAN | c.696C>A p.F232L | Missense Mutation (SNP) | VAF 75/214 reads (35%) | SIFT tolerated (0.07); PolyPhen benign (0.034); catalogued as COSV54098125, COSV54111597; called by muse, mutect2, varscan2
- VIRMA | c.1867G>A p.E623K | Missense Mutation (SNP) | VAF 51/166 reads (31%) | SIFT tolerated (0.06); PolyPhen benign (0.275); catalogued as COSV52582528; called by muse, mutect2, varscan2
- VRTN | c.871G>A p.V291I | Missense Mutation (SNP) | VAF 12/26 reads (46%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as rs769734289, COSV56439380, COSV56439622; called by muse, mutect2, varscan2
- VWA8 | c.591_592del p.E197Dfs*4 | Frame Shift Del (DEL) | VAF 22/56 reads (39%) | catalogued as rs748468790; called by pindel, varscan2
- WARS2 | c.694C>A p.P232T | Missense Mutation (SNP) | VAF 15/38 reads (39%) | SIFT tolerated (0.07); PolyPhen benign (0.444); catalogued as rs750645277, COSV52476106; called by muse, mutect2, varscan2
- WASF3 | c.1037C>T p.P346L | Missense Mutation (SNP) | VAF 23/60 reads (38%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.998); catalogued as rs759410889, COSV58967410; called by muse, mutect2, varscan2
- WDR18 | c.744C>T p.P248= | Splice Region (SNP) | VAF 9/25 reads (36%) | catalogued as rs771858007, COSV52120992; called by muse, mutect2, varscan2
- WDR19 | c.70dup p.T24Nfs*12 | Frame Shift Ins (INS) | VAF 13/46 reads (28%) | catalogued as rs769095843; called by mutect2, pindel, varscan2
- WDR59 | c.140C>A p.P47H | Missense Mutation (SNP) | VAF 10/33 reads (30%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV50933552; called by muse, mutect2, varscan2
- WDR70 | c.164G>A p.R55H | Missense Mutation (SNP) | VAF 10/127 reads (8%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.474); catalogued as rs780037250, COSV99458398; called by muse, mutect2
- WDR70 | c.1883A>G p.Q628R | Missense Mutation (SNP) | VAF 28/91 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV54267652; called by muse, mutect2, varscan2
- WDR81 | c.5396G>A p.R1799H (on ENST00000409644 / NM_001163809.2; = p.R748H on NM_152348.4) | Missense Mutation (SNP) | VAF 9/23 reads (39%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.989); catalogued as rs780532350, COSV58479210; called by muse, mutect2, varscan2
- WNT4 | c.706_708del p.E236del | In Frame Del (DEL) | VAF 10/32 reads (31%) | catalogued as rs1557922250; called by mutect2, pindel, varscan2
- WRN | c.2129T>C p.I710T | Missense Mutation (SNP) | VAF 24/96 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.876); catalogued as COSV53296706; called by muse, mutect2, varscan2
- WSB1 | c.257T>C p.L86S | Missense Mutation (SNP) | VAF 22/50 reads (44%) | SIFT tolerated (0.82); PolyPhen possibly damaging (0.69); catalogued as COSV52214686; called by muse, mutect2
- WWP1 | c.1037C>T p.A346V | Missense Mutation (SNP) | VAF 16/70 reads (23%) | SIFT tolerated (0.4); PolyPhen benign (0.001); catalogued as rs1193846539, COSV55356816; called by muse, mutect2, varscan2
507 further variants in this file (202 protein-altering or splice-affecting, 276 silent, 29 other) are not listed here.
